Somatic mutation profile of tumor specimen TCGA-60-2714-01A (aliquot TCGA-60-2714-01A-01W-0877-08) from TCGA case TCGA-60-2714, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 66.2 years (24,169 days).
Specimen TCGA-60-2714-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fb815897-2f0b-42bc-a4f4-e0b1d74e5f1a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-60-2714-11A (Solid Tissue Normal), aliquot TCGA-60-2714-11A-01D-1522-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d964261d-c8de-409e-8161-c01ff2430b7c

The open-access MAF lists 792 somatic variants for this specimen: 618 protein-altering or splice-affecting, 158 silent, 16 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 549, Silent 158, Nonsense Mutation 34, Splice Site 14, Frame Shift Del 12, RNA 7, Frame Shift Ins 6, Intron 6, Splice Region 3, 3'UTR 2, 5'Flank 1.

Variants (750 of 792; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL6A3 | c.1393C>T p.R465* | Nonsense Mutation (SNP) | VAF 24/153 reads (16%) | catalogued as rs121434554, CM021076, COSV55086452; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.392A>T p.N131I | Missense Mutation (SNP) | VAF 37/80 reads (46%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1131691037, CM087281, CM159290, COSV52670715, COSV52718021, COSV53252418; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ABCA6 | c.4165G>A p.A1389T | Missense Mutation (SNP) | VAF 29/235 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.2); catalogued as COSV99447741; called by muse, varscan2
- ABCA6 | c.4114A>T p.R1372W | Missense Mutation (SNP) | VAF 33/146 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs142075639; called by muse, varscan2
- ABCC4 | c.2218A>T p.N740Y | Missense Mutation (SNP) | VAF 128/531 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.492); catalogued as COSV100972802; called by muse, mutect2, varscan2
- ABRA | c.967C>A p.H323N | Missense Mutation (SNP) | VAF 141/260 reads (54%) | SIFT tolerated (0.14); PolyPhen benign (0.086); catalogued as COSV100357660; called by muse, mutect2, varscan2
- AC011448.1 | c.24G>T p.Q8H | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV99389289; called by muse, mutect2
- ACP3 | c.678G>T p.W226C | Missense Mutation (SNP) | VAF 41/379 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100313591; called by muse, mutect2, varscan2
- ACSM2A | c.1212del p.G405Afs*16 (on ENST00000219054; = p.G326Afs*16 on NM_001308169.2) | Frame Shift Del (DEL) | VAF 92/280 reads (33%) | catalogued as rs755296455; called by mutect2, pindel, varscan2
- ACTG2 | c.865G>T p.D289Y | Missense Mutation (SNP) | VAF 95/190 reads (50%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (1); catalogued as COSV100609515; called by muse, mutect2, varscan2
- ADAMTS1 | c.2186G>T p.G729V | Missense Mutation (SNP) | VAF 37/67 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99536542; called by muse, mutect2, varscan2
- ADCY2 | c.1120G>C p.D374H | Missense Mutation (SNP) | VAF 203/629 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV100604170; called by muse, mutect2, varscan2
- ADCY5 | c.2538C>A p.F846L | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.028); catalogued as COSV100568271, COSV59199932; called by muse, mutect2, varscan2
- ADCYAP1R1 | c.1376C>A p.S459Y | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100416959, COSV58445671; called by muse, mutect2, varscan2
- ADGRA3 | c.3532G>A p.G1178R | Missense Mutation (SNP) | VAF 14/179 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.497); catalogued as COSV99293799; called by muse, mutect2
- ADGRB3 | c.2951T>C p.L984S | Missense Mutation (SNP) | VAF 175/291 reads (60%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99486902; called by muse, mutect2, varscan2
- ADGRL2 | c.2981T>C p.F994S (on ENST00000370717 / NM_001366005.1; = p.F981S on NM_012302.4) | Missense Mutation (SNP) | VAF 14/141 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99591636; called by muse, mutect2
- ADGRV1 | c.9472G>C p.D3158H | Missense Mutation (SNP) | VAF 54/218 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV67995946; called by muse, mutect2, varscan2
- ADIPOR1 | c.264G>T p.W88C | Missense Mutation (SNP) | VAF 25/155 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV100579674; called by muse, mutect2, varscan2
- AFF3 | c.1092-2A>T p.X364_splice | Splice Site (SNP) | VAF 79/720 reads (11%) | catalogued as COSV100420126; called by muse, mutect2, varscan2
- AGAP3 | c.1241G>A p.G414D (on ENST00000622464; = p.G450D on NM_031946.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV101257440; called by muse, varscan2
- AGMO | c.1308G>A p.M436I | Missense Mutation (SNP) | VAF 26/203 reads (13%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV100694613, COSV100694753; called by muse, mutect2, varscan2
- AGPAT4 | c.178+2T>A p.X60_splice | Splice Site (SNP) | VAF 24/126 reads (19%) | catalogued as COSV100212109; called by muse, mutect2, varscan2
- AHNAK2 | c.1381G>A p.G461R | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.549); catalogued as rs754074625, COSV100318997, COSV100319122; called by muse, mutect2, varscan2
- AK5 | c.832T>A p.F278I (on ENST00000354567 / NM_174858.3; = p.F252I on NM_012093.4) | Missense Mutation (SNP) | VAF 31/175 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100643399; called by muse, mutect2, varscan2
- ALDOB | c.58G>T p.A20S | Missense Mutation (SNP) | VAF 33/147 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as rs575202673, COSV100878926; called by muse, mutect2, varscan2
- ALPK3 | c.2077C>T p.Q693* | Nonsense Mutation (SNP) | VAF 17/77 reads (22%) | catalogued as COSV99362024; called by muse, mutect2, varscan2
- ANKRD1 | c.703G>A p.A235T | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.8); catalogued as rs768116191, COSV100865331; called by muse, mutect2, varscan2
- ANKRD17 | c.3212C>T p.P1071L | Missense Mutation (SNP) | VAF 19/256 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as COSV100430006; called by muse, mutect2
- ANO5 | c.1817G>A p.C606Y | Missense Mutation (SNP) | VAF 39/227 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100202237; called by muse, mutect2, varscan2
- APAF1 | c.1481C>T p.A494V (on ENST00000551964 / NM_181861.2; = p.A483V on NM_001160.3) | Missense Mutation (SNP) | VAF 69/163 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs143963802; called by muse, mutect2, varscan2
- APCS | c.418C>A p.Q140K | Missense Mutation (SNP) | VAF 49/167 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99661521; called by muse, mutect2, varscan2
- APOB | c.12325C>A p.Q4109K | Missense Mutation (SNP) | VAF 174/269 reads (65%) | SIFT tolerated (0.1); PolyPhen benign (0.067); catalogued as rs928519754, COSV99268179; called by muse, mutect2, varscan2
- AQP3 | c.797G>C p.G266A | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.65); PolyPhen probably damaging (0.998); catalogued as COSV99955703; called by muse, mutect2, varscan2
- ARHGAP30 | c.2977G>A p.G993S (on ENST00000368013 / NM_001025598.2; = p.G782S on NM_181720.3) | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs746429914, COSV100920510; called by muse, mutect2, varscan2
- ARHGAP5 | c.225G>T p.W75C | Missense Mutation (SNP) | VAF 49/366 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100565709; called by muse, mutect2, varscan2
- ASB17 | c.857G>A p.R286H | Missense Mutation (SNP) | VAF 52/306 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.392); catalogued as rs149522654; called by muse, mutect2, varscan2
- ASTN2 | c.1081G>A p.A361T | Missense Mutation (SNP) | VAF 21/202 reads (10%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as rs753224709, COSV100529938; called by muse, mutect2, varscan2
- ASTN2 | c.826C>A p.H276N | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.121); catalogued as COSV57782002; called by muse, mutect2
- ASXL3 | c.2540C>A p.P847H | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.338); catalogued as COSV99326654; called by muse, mutect2, varscan2
- ATP2B2 | c.1164G>T p.K388N (on ENST00000352432; = p.K354N on NM_001683.5) | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV100660502; called by muse, mutect2, varscan2
- ATP9A | c.562C>T p.R188W | Missense Mutation (SNP) | VAF 48/148 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58765058; called by muse, mutect2, varscan2
- AZGP1 | c.778G>A p.G260S | Missense Mutation (SNP) | VAF 42/216 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.758); catalogued as COSV99448223, COSV99448237; called by muse, mutect2, varscan2
- B4GALNT2 | c.1004A>G p.K335R | Missense Mutation (SNP) | VAF 66/269 reads (25%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.526); catalogued as rs1253018157, COSV100302773; called by muse, mutect2, varscan2
- BAAT | c.842C>G p.S281C | Missense Mutation (SNP) | VAF 32/237 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.166); catalogued as COSV52289965, COSV99408683; called by muse, mutect2, varscan2
- BARD1 | c.2111G>T p.S704I | Missense Mutation (SNP) | VAF 62/111 reads (56%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as rs764477334, COSV99639890; ClinVar: likely benign; called by muse, mutect2, varscan2
- BAZ2A | c.3821G>A p.S1274N | Missense Mutation (SNP) | VAF 17/163 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); catalogued as COSV99467714; called by muse, mutect2, varscan2
- BCAN | c.1294C>A p.L432I | Missense Mutation (SNP) | VAF 44/148 reads (30%) | SIFT tolerated (0.27); PolyPhen benign (0.164); catalogued as COSV61259816; called by muse, mutect2, varscan2
- BCO1 | c.590T>A p.V197E | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.776); catalogued as COSV99258688; called by muse, mutect2, varscan2
- BNC2 | c.1172C>A p.T391N | Missense Mutation (SNP) | VAF 28/130 reads (22%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV101034489; called by muse, mutect2, varscan2
- BRCA1 | c.3404A>T p.Q1135L | Missense Mutation (SNP) | VAF 49/435 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.465); catalogued as COSV100525129; called by muse, mutect2, varscan2
- BRD8 | c.506-2A>T p.X169_splice | Splice Site (SNP) | VAF 36/89 reads (40%) | catalogued as COSV99137673; called by muse, mutect2, varscan2
- BRWD3 | c.4362C>A p.S1454R | Missense Mutation (SNP) | VAF 728/1652 reads (44%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.655); catalogued as COSV100956561; called by muse, varscan2
- BSND | c.548+1G>A p.X183_splice | Splice Site (SNP) | VAF 35/68 reads (51%) | catalogued as rs765766484, COSV100987661; called by muse, mutect2, varscan2
- BTAF1 | c.1309G>C p.E437Q | Missense Mutation (SNP) | VAF 14/192 reads (7%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as COSV99795847; called by muse, mutect2
- BTN1A1 | c.1436C>A p.P479H | Missense Mutation (SNP) | VAF 95/152 reads (63%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.838); catalogued as COSV99764564; called by muse, mutect2, varscan2
- BUB1 | c.3075G>T p.L1025F | Missense Mutation (SNP) | VAF 30/55 reads (55%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.836); catalogued as COSV100241672; called by muse, mutect2, varscan2
- BUD31 | c.412G>T p.G138C | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99464575; called by muse, mutect2, varscan2
- C22orf31 | c.167C>G p.P56R | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.509); catalogued as COSV99326522; called by muse, mutect2
- C2CD2 | c.1634A>T p.E545V | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.36); catalogued as COSV100298426; called by muse, mutect2, varscan2
- C2orf16 | c.2497G>A p.E833K | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.66); catalogued as COSV100821033; called by muse, mutect2, varscan2
- C3AR1 | c.731G>T p.R244M | Missense Mutation (SNP) | VAF 24/260 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV99368993; called by muse, mutect2
- C6 | c.411G>T p.E137D | Missense Mutation (SNP) | VAF 187/499 reads (37%) | SIFT tolerated (0.3); PolyPhen benign (0.015); catalogued as rs142045537; called by muse, mutect2, varscan2
- C9 | c.153G>A p.W51* | Nonsense Mutation (SNP) | VAF 47/314 reads (15%) | catalogued as COSV99662567; called by muse, mutect2, varscan2
- C9orf131 | c.2966C>A p.P989H | Missense Mutation (SNP) | VAF 69/188 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.443); catalogued as COSV100398322; called by muse, varscan2
- CACNA1C | c.3717G>T p.Q1239H | Missense Mutation (SNP) | VAF 65/196 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100222350; called by muse, mutect2, varscan2
- CACNA1E | c.5149C>G p.L1717V | Missense Mutation (SNP) | VAF 134/795 reads (17%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV100705409; called by muse, mutect2, varscan2
- CAMSAP2 | c.83C>G p.S28C | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.125); catalogued as COSV99374358; called by muse, mutect2, varscan2
- CARD17 | c.291T>A p.N97K | Missense Mutation (SNP) | VAF 38/564 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV100995287; called by muse, mutect2
- CCDC157 | c.458C>A p.P153H | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100199848; called by muse, mutect2, varscan2
- CCSER2 | c.1913A>T p.Y638F | Missense Mutation (SNP) | VAF 23/233 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.012); catalogued as rs753359820, COSV99826537; called by muse, mutect2, varscan2
- CD200R1 | c.188C>A p.P63H (on ENST00000471858 / NM_170780.3; = p.P86H on NM_138806.4) | Missense Mutation (SNP) | VAF 127/402 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.062); catalogued as COSV55600921, COSV99867842; called by muse, mutect2, varscan2
- CD300LD | c.65C>A p.T22N | Missense Mutation (SNP) | VAF 17/151 reads (11%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.518); catalogued as COSV100032663; called by muse, mutect2, varscan2
- CDC20B | c.712G>C p.D238H | Missense Mutation (SNP) | VAF 94/216 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99697426; called by muse, mutect2, varscan2
- CDH10 | c.1975G>T p.D659Y | Missense Mutation (SNP) | VAF 83/218 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100050393, COSV52570059; called by muse, mutect2, varscan2
- CDH10 | c.1624G>C p.D542H | Missense Mutation (SNP) | VAF 50/221 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100053159; called by muse, mutect2, varscan2
- CDH18 | c.2127C>A p.S709R | Missense Mutation (SNP) | VAF 62/198 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.139); catalogued as COSV99935584; called by muse, mutect2, varscan2
- CDHR1 | c.334G>T p.D112Y | Missense Mutation (SNP) | VAF 30/142 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100259394; called by muse, mutect2, varscan2
- CELSR2 | c.6179G>T p.R2060L | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.03); catalogued as COSV99603466; called by muse, mutect2, varscan2
- CEMIP | c.1879C>A p.H627N | Missense Mutation (SNP) | VAF 33/179 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99587310; called by muse, mutect2, varscan2
- CFAP58 | c.217G>T p.V73L | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT tolerated (0.34); PolyPhen benign (0.009); catalogued as COSV100459129; called by muse, mutect2, varscan2
- CFAP61 | c.2911G>T p.D971Y | Missense Mutation (SNP) | VAF 121/444 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99846687; called by muse, mutect2, varscan2
- CFAP91 | c.1313G>T p.R438M | Missense Mutation (SNP) | VAF 174/515 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV99847513; called by muse, mutect2, varscan2
- CFAP94 | c.1576A>G p.I526V (on ENST00000320267 / NM_001352064.2; = p.I532V on NM_018272.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT tolerated (0.45); PolyPhen benign (0.007); catalogued as COSV100209758; called by muse, mutect2
- CFH | c.254G>T p.C85F | Missense Mutation (SNP) | VAF 34/208 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100661454, COSV100661655; called by muse, mutect2, varscan2
- CHMP4C | c.353C>T p.S118F | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.035); catalogued as COSV51928834; called by muse, mutect2, varscan2
- CLCN4 | c.688G>T p.V230L | Missense Mutation (SNP) | VAF 27/92 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.131); catalogued as COSV101074075; called by muse, mutect2, varscan2
- CLN5 | c.449G>T p.R150L | Missense Mutation (SNP) | VAF 78/239 reads (33%) | SIFT tolerated (0.26); PolyPhen benign (0.156); catalogued as rs1014000261, COSV66283955; called by muse, mutect2, varscan2
- CLVS1 | c.283G>A p.A95T | Missense Mutation (SNP) | VAF 15/160 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.27); catalogued as COSV100369836, COSV100370711; called by muse, mutect2, varscan2
- CNGB3 | c.367G>C p.V123L | Missense Mutation (SNP) | VAF 107/459 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as rs1403535781, COSV100183095; called by muse, mutect2, varscan2
- CNKSR2 | c.1268G>T p.S423I | Missense Mutation (SNP) | VAF 64/211 reads (30%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as COSV99669816; called by muse, mutect2, varscan2
- CNKSR2 | c.2504T>A p.L835Q | Missense Mutation (SNP) | VAF 25/171 reads (15%) | SIFT tolerated (0.63); PolyPhen benign (0.001); catalogued as COSV99669818; called by muse, mutect2, varscan2
- CNNM1 | c.2368C>G p.L790V | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.222); catalogued as rs754147700, COSV100763992; called by muse, mutect2, varscan2
- CNTLN | c.1405G>T p.E469* | Nonsense Mutation (SNP) | VAF 64/430 reads (15%) | catalogued as COSV99265738; called by muse, mutect2, varscan2
- CNTNAP2 | c.2262G>T p.K754N | Missense Mutation (SNP) | VAF 39/187 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100665030, COSV62257249; called by muse, mutect2, varscan2
- CNTNAP2 | c.2785G>T p.G929C | Missense Mutation (SNP) | VAF 32/147 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as COSV100665060, COSV100673046; called by muse, mutect2, varscan2
- COL14A1 | c.2977G>T p.E993* | Nonsense Mutation (SNP) | VAF 136/263 reads (52%) | catalogued as COSV99920720; called by muse, mutect2, varscan2
- COL3A1 | c.2730C>A p.N910K | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT tolerated (0.12); PolyPhen benign (0.01); catalogued as COSV100483748; called by muse, mutect2, varscan2
- COL6A3 | c.4064C>A p.P1355Q | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.65); catalogued as COSV99801569; called by muse, mutect2, varscan2
- COL6A5 | c.6166G>A p.A2056T (on ENST00000312481; = p.A2052T on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/364 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.038); catalogued as COSV55215922; called by muse, mutect2
- CPD | c.2224G>A p.V742M | Missense Mutation (SNP) | VAF 34/406 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56711787; called by muse, mutect2
- CPE | c.1213+1G>T p.X405_splice | Splice Site (SNP) | VAF 13/89 reads (15%) | catalogued as COSV101291734; called by muse, mutect2, varscan2
- CRX | c.749C>G p.P250R | Missense Mutation (SNP) | VAF 58/150 reads (39%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.977); catalogued as COSV99704658; called by muse, mutect2, varscan2
- CRYBB1 | c.95C>T p.S32F | Missense Mutation (SNP) | VAF 52/249 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.205); catalogued as COSV99316221; called by muse, mutect2, varscan2
- CSF2RB | c.2398C>A p.P800T | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV99454477; called by muse, mutect2, varscan2
- CSMD2 | c.8389C>T p.R2797W | Missense Mutation (SNP) | VAF 39/133 reads (29%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.927); catalogued as rs746116665, COSV53890915; called by muse, mutect2, varscan2
- CSMD2 | c.1494C>A p.F498L | Missense Mutation (SNP) | VAF 98/307 reads (32%) | SIFT tolerated (0.89); PolyPhen benign (0.023); catalogued as COSV99595518; called by muse, mutect2, varscan2
- CSMD3 | c.9002C>A p.P3001H (on ENST00000297405 / NM_001363185.1; = p.P2832H on NM_052900.3) | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99829319, COSV99848060; called by muse, mutect2
- CSMD3 | c.7937C>A p.T2646K (on ENST00000297405 / NM_001363185.1; = p.T2542K on NM_052900.3) | Missense Mutation (SNP) | VAF 43/247 reads (17%) | SIFT tolerated (0.94); PolyPhen possibly damaging (0.506); catalogued as COSV99848065; called by muse, mutect2, varscan2
- CSMD3 | c.1509-1G>T p.X503_splice (on ENST00000297405 / NM_001363185.1; = p.X399_splice on NM_052900.3) | Splice Site (SNP) | VAF 63/383 reads (16%) | catalogued as COSV99848066; called by muse, mutect2, varscan2
- CTNNA3 | c.354G>T p.R118S | Missense Mutation (SNP) | VAF 91/303 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100373890; called by muse, mutect2, varscan2
- CTNNA3 | c.353G>T p.R118M | Missense Mutation (SNP) | VAF 86/304 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100373894; called by muse, varscan2
- CTNND2 | c.1310T>A p.L437H | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.707); catalogued as COSV100481157; called by muse, mutect2, varscan2
- CUBN | c.7606A>G p.I2536V | Missense Mutation (SNP) | VAF 10/142 reads (7%) | SIFT tolerated (0.98); PolyPhen benign (0.019); catalogued as COSV100913565; called by muse, mutect2
- CUL3 | c.1843-1G>T p.X615_splice | Splice Site (SNP) | VAF 43/133 reads (32%) | catalogued as COSV100024780; called by muse, mutect2, varscan2
- CUTC | c.192G>T p.M64I | Missense Mutation (SNP) | VAF 31/155 reads (20%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV100976188; called by muse, mutect2, varscan2
- CUX2 | c.3670C>A p.R1224S | Missense Mutation (SNP) | VAF 28/57 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as COSV55627829, COSV99920801; called by muse, mutect2, varscan2
- CYB561 | c.463C>G p.R155G | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.35); PolyPhen benign (0.017); catalogued as COSV100669192; called by muse, mutect2, varscan2
- CYP2R1 | c.322G>T p.D108Y | Missense Mutation (SNP) | VAF 8/93 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100585006; called by muse, mutect2
- CYP8B1 | c.499G>T p.D167Y | Missense Mutation (SNP) | VAF 27/128 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100296301; called by muse, mutect2, varscan2
- DBI | c.128-2A>C p.X43_splice (on ENST00000355857 / NM_001079862.3; = p.X60_splice on NM_020548.8 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 9/49 reads (18%) | catalogued as COSV100276055; called by muse, mutect2, varscan2
- DCAF17 | c.1205C>T p.T402I | Missense Mutation (SNP) | VAF 29/59 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs764124723, COSV100266393; called by muse, mutect2, varscan2
- DCAF8L1 | c.179T>G p.L60R | Missense Mutation (SNP) | VAF 50/214 reads (23%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0); catalogued as COSV101491548; called by muse, mutect2, varscan2
- DCC | c.2920A>C p.N974H | Missense Mutation (SNP) | VAF 79/283 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100503167; called by muse, mutect2, varscan2
- DDC | c.856C>A p.H286N | Missense Mutation (SNP) | VAF 43/223 reads (19%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.843); catalogued as COSV100779756; called by muse, mutect2, varscan2
- DDX58 | c.2450C>T p.A817V | Missense Mutation (SNP) | VAF 12/274 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.017); catalogued as COSV100008669; called by muse, mutect2
- DDX59 | c.1057G>T p.D353Y | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100494709; called by muse, mutect2, varscan2
- DENND2A | c.451C>T p.R151C | Missense Mutation (SNP) | VAF 19/205 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.586); catalogued as rs868619288, COSV52058672; called by muse, mutect2, varscan2
- DIAPH2 | c.2771T>C p.V924A | Missense Mutation (SNP) | VAF 29/101 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV100235403; called by muse, mutect2, varscan2
- DNAH11 | c.856G>T p.E286* | Nonsense Mutation (SNP) | VAF 8/43 reads (19%) | catalogued as COSV100176684; called by muse, mutect2, varscan2
- DNAH17 | c.3436C>G p.L1146V | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs372653772, COSV101103506; called by muse, mutect2, varscan2
- DNAH7 | c.7308G>T p.K2436N | Missense Mutation (SNP) | VAF 87/173 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV100417626; called by muse, mutect2, varscan2
- DNAJC5B | c.163C>A p.P55T | Missense Mutation (SNP) | VAF 181/555 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.816); catalogued as COSV52538334, COSV99395949; called by muse, mutect2, varscan2
- DOCK2 | c.4583C>A p.S1528Y | Missense Mutation (SNP) | VAF 108/484 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99915544; called by muse, mutect2, varscan2
- DPP4 | c.1379C>T p.S460L | Missense Mutation (SNP) | VAF 63/161 reads (39%) | SIFT tolerated (0.62); PolyPhen benign (0.105); catalogued as COSV100859106; called by muse, mutect2, varscan2
- DPYS | c.271C>T p.L91F | Missense Mutation (SNP) | VAF 78/291 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as rs910567054, COSV100680140, COSV99080288; called by muse, mutect2, varscan2
- DSG2 | c.2229A>C p.E743D | Missense Mutation (SNP) | VAF 22/195 reads (11%) | SIFT tolerated (0.36); PolyPhen benign (0.011); catalogued as COSV99853565; called by muse, mutect2, varscan2
- DUSP6 | c.665C>A p.S222Y | Missense Mutation (SNP) | VAF 40/95 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54377940, COSV99684153; called by muse, mutect2, varscan2
- EDIL3 | c.152C>G p.P51R | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV99679190; called by muse, mutect2, varscan2
- EFL1 | c.2393A>T p.E798V | Missense Mutation (SNP) | VAF 25/111 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.118); catalogued as COSV51607522; called by muse, mutect2, varscan2
- EFR3A | c.1723G>T p.A575S | Missense Mutation (SNP) | VAF 41/338 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.049); catalogued as rs776395415, COSV99603628; called by muse, mutect2, varscan2
- EHHADH | c.843G>T p.W281C | Missense Mutation (SNP) | VAF 189/483 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99213368; called by muse, mutect2, varscan2
- EMSY | c.1749G>T p.K583N | Missense Mutation (SNP) | VAF 38/379 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100596083; called by muse, mutect2
- ENAM | c.2407C>A p.Q803K | Missense Mutation (SNP) | VAF 46/325 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.049); catalogued as COSV101253346; called by muse, mutect2, varscan2
- ENTHD1 | c.1276G>T p.D426Y | Missense Mutation (SNP) | VAF 57/132 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV100289145; called by muse, mutect2, varscan2
- EOMES | c.1513C>G p.P505A | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV99842318; called by muse, mutect2, varscan2
- EP300 | c.995C>T p.P332L | Missense Mutation (SNP) | VAF 71/263 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs754108081, COSV99609891; called by muse, mutect2, varscan2
- EPC2 | c.535G>A p.V179M | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.652); catalogued as COSV99310220; called by muse, mutect2, varscan2
- EPHA6 | c.1692T>A p.N564K | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV101065589; called by muse, mutect2, varscan2
- EPHA6 | c.3280G>A p.D1094N | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs890362586, COSV101065592; called by muse, mutect2, varscan2
- EPS15L1 | c.1632G>C p.R544S | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.786); catalogued as COSV99933726; called by muse, mutect2, varscan2
- ERICH3 | c.1589del p.P530Lfs*9 | Frame Shift Del (DEL) | VAF 81/406 reads (20%) | catalogued as COSV58622639; called by mutect2, pindel, varscan2
- ESRP1 | c.1294G>T p.V432L | Missense Mutation (SNP) | VAF 47/450 reads (10%) | SIFT tolerated (0.78); PolyPhen benign (0.028); catalogued as COSV100619664; called by muse, mutect2, varscan2
- ESRP1 | c.1543G>C p.D515H | Missense Mutation (SNP) | VAF 116/219 reads (53%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as COSV100619667, COSV64409200; called by muse, mutect2, varscan2
- ETFA | c.186+1G>T p.X62_splice | Splice Site (SNP) | VAF 31/134 reads (23%) | catalogued as COSV99144275; called by muse, mutect2, varscan2
- ETV3L | c.868G>T p.A290S | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.142); catalogued as rs935989348, COSV101485618; called by mutect2, varscan2
- ETV3L | c.867G>T p.L289F | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.567); catalogued as rs771783360, COSV101485619; called by muse, mutect2, varscan2
- EXOC4 | c.1654A>C p.T552P | Missense Mutation (SNP) | VAF 28/133 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.216); catalogued as COSV99555817; called by muse, mutect2, varscan2
- EXTL3 | c.493G>C p.D165H | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.364); catalogued as rs375243395, COSV99594352; called by muse, mutect2, varscan2
- EZH2 | c.2053C>G p.R685G (on ENST00000460911 / NM_001203247.2; = p.R690G on NM_004456.5) | Missense Mutation (SNP) | VAF 119/800 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV100236106, COSV100236878, COSV57445951; called by muse, mutect2, varscan2
- FAM135B | c.3565A>G p.T1189A | Missense Mutation (SNP) | VAF 44/444 reads (10%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.526); catalogued as COSV99427797; called by muse, mutect2
- FAM170A | c.292C>G p.R98G | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0.04); catalogued as COSV100089350, COSV58925855; called by muse, mutect2, varscan2
- FAM214B | c.628A>T p.S210C | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.466); catalogued as COSV100521447; called by muse, mutect2, varscan2
- FAM47A | c.2185G>T p.V729F | Missense Mutation (SNP) | VAF 84/287 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as COSV100650092, COSV60494022; called by muse, mutect2, varscan2
- FAM76B | c.971C>G p.S324* | Nonsense Mutation (SNP) | VAF 14/147 reads (10%) | catalogued as COSV100716571; called by muse, mutect2
- FANCI | c.3460C>T p.P1154S (on ENST00000310775 / NM_001376911.1; = p.P1094S on NM_018193.3) | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100168582; called by muse, mutect2, varscan2
- FAP | c.1769G>A p.R590Q | Missense Mutation (SNP) | VAF 64/804 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.533); catalogued as rs747747073, COSV51861339; called by muse, mutect2
- FAT1 | c.5638G>A p.A1880T | Missense Mutation (SNP) | VAF 33/156 reads (21%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV101499651; called by muse, mutect2, varscan2
- FAT3 | c.10217G>T p.R3406L | Missense Mutation (SNP) | VAF 32/148 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53103909; called by muse, mutect2, varscan2
- FAT3 | c.12594del p.A4199Pfs*65 | Frame Shift Del (DEL) | VAF 9/20 reads (45%) | catalogued as COSV99970537; called by mutect2, pindel, varscan2
- FAT4 | c.4228G>T p.V1410L | Missense Mutation (SNP) | VAF 49/150 reads (33%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.98); catalogued as rs781736766, COSV101272852, COSV67881199, COSV67899529; called by muse, mutect2, varscan2
- FAT4 | c.9633T>A p.S3211R | Missense Mutation (SNP) | VAF 12/214 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100630252; called by muse, mutect2
- FBLN2 | c.2330C>A p.P777Q | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.62); PolyPhen benign (0.06); catalogued as COSV99852698; called by muse, mutect2, varscan2
- FBXO8 | c.200G>T p.G67V | Missense Mutation (SNP) | VAF 22/233 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.333); catalogued as COSV101183747; called by muse, mutect2
- FCGR1A | c.149G>T p.G50V | Missense Mutation (SNP) | VAF 47/134 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.865); catalogued as COSV100977316; called by muse, mutect2, varscan2
- FCN1 | c.729T>A p.S243R | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.154); catalogued as COSV100878973; called by muse, mutect2, varscan2
- FCN2 | c.231dup p.G78Wfs*57 | Frame Shift Ins (INS) | VAF 3/21 reads (14%) | catalogued as COSV99391224; called by mutect2, pindel, varscan2
- FEM1B | c.1495G>T p.D499Y | Missense Mutation (SNP) | VAF 58/262 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100183766, COSV60988396; called by muse, mutect2, varscan2
- FER1L6 | c.3380C>T p.S1127F | Missense Mutation (SNP) | VAF 268/531 reads (50%) | SIFT tolerated (0.15); PolyPhen benign (0.021); catalogued as COSV101206206; called by muse, mutect2, varscan2
- FHL5 | c.715T>C p.C239R | Missense Mutation (SNP) | VAF 57/118 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.348); catalogued as COSV100459812; called by muse, mutect2, varscan2
- FLG | c.2863C>T p.H955Y | Missense Mutation (SNP) | VAF 28/311 reads (9%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.911); catalogued as COSV100912232; called by muse, mutect2
- FMO3 | c.1434G>T p.Q478H | Missense Mutation (SNP) | VAF 20/188 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.489); catalogued as COSV100882557; called by muse, mutect2, varscan2
- FOXI1 | c.1011G>T p.W337C | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.936); catalogued as COSV100089619; called by muse, mutect2, varscan2
- FOXN3 | c.587G>C p.R196T | Missense Mutation (SNP) | VAF 15/162 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54307740, COSV99727504; called by muse, mutect2, varscan2
- FRMPD2 | c.1426C>A p.Q476K | Missense Mutation (SNP) | VAF 163/459 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as COSV100564208; called by muse, mutect2, varscan2
- FSD2 | c.75C>A p.D25E | Missense Mutation (SNP) | VAF 49/183 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as COSV100575294; called by muse, mutect2, varscan2
- FSHR | c.862C>A p.L288I | Missense Mutation (SNP) | VAF 153/340 reads (45%) | SIFT tolerated (0.14); PolyPhen benign (0.011); catalogued as COSV100438116; called by muse, mutect2, varscan2
- G6PC | c.34G>T p.G12W | Missense Mutation (SNP) | VAF 14/107 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99520979; called by muse, mutect2, varscan2
- G6PC | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 15/107 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs775755718, COSV99520981; called by muse, mutect2, varscan2
- GAD1 | c.1697T>A p.F566Y | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100828020; called by muse, mutect2, varscan2
- GAD2 | c.975A>C p.K325N | Missense Mutation (SNP) | VAF 31/162 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as COSV52169940, COSV99394070; called by muse, mutect2, varscan2
- GALC | c.1850A>T p.Y617F | Missense Mutation (SNP) | VAF 73/695 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV99730592; called by muse, mutect2, varscan2
- GALC | c.399G>T p.L133F | Missense Mutation (SNP) | VAF 19/215 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV99730598; called by muse, mutect2
- GANC | c.879G>T p.E293D | Missense Mutation (SNP) | VAF 10/53 reads (19%) | PolyPhen benign (0.001); catalogued as COSV100530570, COSV100531271; called by muse, mutect2
- GBP5 | c.634C>A p.Q212K | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as COSV100600170; called by muse, mutect2, varscan2
- GCN1 | c.7728G>T p.W2576C | Missense Mutation (SNP) | VAF 28/268 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.96); catalogued as COSV100326011; called by muse, mutect2, varscan2
- GGH | c.209G>C p.R70T | Missense Mutation (SNP) | VAF 17/106 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99479039, COSV99479057; called by muse, varscan2
- GIMAP5 | c.472G>A p.G158S | Missense Mutation (SNP) | VAF 140/656 reads (21%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.455); catalogued as rs138178760; called by mutect2, varscan2
- GINM1 | c.161G>T p.G54V | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV100805373; called by muse, mutect2, varscan2
- GK2 | c.430C>A p.P144T | Missense Mutation (SNP) | VAF 53/494 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100726043; called by muse, mutect2, varscan2
- GLOD4 | c.657C>G p.F219L (on ENST00000301328 / NM_001366247.1; = p.F204L on NM_016080.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 134/1432 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100022821; called by muse, mutect2
- GNAT3 | c.319C>A p.L107I | Missense Mutation (SNP) | VAF 145/679 reads (21%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.999); catalogued as rs780587404, COSV101242420; called by muse, mutect2, varscan2
- GOLGB1 | c.6862G>A p.E2288K | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.029); catalogued as COSV61463876, COSV61463941; called by muse, mutect2, varscan2
- GPAT3 | c.226G>T p.E76* | Nonsense Mutation (SNP) | VAF 36/139 reads (26%) | catalogued as rs1244789326, COSV100023300; called by muse, mutect2, varscan2
- GPN3 | c.175G>A p.E59K | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.166); catalogued as rs1208040516, COSV99959985; called by muse, mutect2, varscan2
- GPR139 | c.1005C>G p.I335M | Missense Mutation (SNP) | VAF 22/552 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.924); catalogued as COSV58504970; called by muse, mutect2
- GPR22 | c.950T>A p.L317* | Nonsense Mutation (SNP) | VAF 28/147 reads (19%) | catalogued as COSV99773233; called by muse, mutect2, varscan2
- GPRC6A | c.1586G>T p.G529V | Missense Mutation (SNP) | VAF 43/165 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100114795; called by muse, mutect2, varscan2
- GPRC6A | c.1194G>C p.M398I | Missense Mutation (SNP) | VAF 37/147 reads (25%) | SIFT tolerated (0.37); PolyPhen benign (0.02); catalogued as COSV100114223, COSV100114798; called by muse, mutect2, varscan2
- GRIA4 | c.1018G>A p.G340S | Missense Mutation (SNP) | VAF 94/158 reads (59%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV99234563; called by muse, mutect2, varscan2
- GRID2 | c.1955T>G p.L652R | Missense Mutation (SNP) | VAF 40/368 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56190673, COSV99943763; called by muse, mutect2, varscan2
- GRIK1 | c.2709C>A p.N903K (on ENST00000327783 / NM_001330994.2; = p.N859K on NM_175611.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 74/184 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.173); catalogued as COSV100584509; called by muse, mutect2, varscan2
- GRIN2A | c.1556C>G p.S519C | Missense Mutation (SNP) | VAF 477/823 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as COSV100411098; called by muse, mutect2, varscan2
- GRIP2 | c.742C>T p.L248F (on ENST00000619221; = p.L151F on NM_001080423.4) | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99817684; called by muse, mutect2, varscan2
- GRM1 | c.79G>C p.V27L | Missense Mutation (SNP) | VAF 89/211 reads (42%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as COSV99269023; called by muse, mutect2, varscan2
- GRM7 | c.1139G>C p.G380A | Missense Mutation (SNP) | VAF 16/184 reads (9%) | SIFT tolerated (0.67); PolyPhen benign (0.007); catalogued as COSV100738726; called by muse, mutect2
- GYPE | c.71G>A p.G24D | Missense Mutation (SNP) | VAF 526/2613 reads (20%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0.015); catalogued as rs1273646053, COSV62262121; called by muse, mutect2, varscan2
- H2AC6 | c.364G>A p.E122K | Missense Mutation (SNP) | VAF 36/167 reads (22%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as COSV58416030, COSV58417289; called by muse, mutect2, varscan2
- HAUS6 | c.1764G>C p.L588F | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.683); catalogued as COSV65840237; called by muse, varscan2
- HBD | c.350G>T p.R117L | Missense Mutation (SNP) | VAF 45/167 reads (27%) | SIFT tolerated (0.31); PolyPhen benign (0.04); catalogued as CM023082, CM032939, COSV53082154, COSV99496881; called by muse, mutect2, varscan2
- HEPACAM | c.149C>T p.S50L | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.353); catalogued as rs140829989; called by mutect2, varscan2
- HIRA | c.1624A>G p.T542A | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV99600024; called by muse, mutect2, varscan2
- HLTF | c.61G>T p.V21F | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.121); catalogued as COSV100027149; called by muse, mutect2, varscan2
- HMGCL | c.750G>T p.Q250H | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52525712, COSV99354108; called by muse, mutect2, varscan2
- HOXD12 | c.47T>C p.L16P | Missense Mutation (SNP) | VAF 17/30 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101184356; called by muse, mutect2, varscan2
- HRNR | c.7068G>C p.Q2356H | Missense Mutation (SNP) | VAF 22/547 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.021); catalogued as COSV100912871, COSV100913970; called by muse, mutect2
- HSPA6 | c.1605G>T p.R535S | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.633); catalogued as COSV100553860; called by mutect2, varscan2
- HTR1E | c.508C>A p.P170T | Missense Mutation (SNP) | VAF 116/209 reads (56%) | SIFT tolerated (0.57); PolyPhen benign (0.158); catalogued as rs760216096, COSV100541310; called by muse, mutect2, varscan2
- HTRA3 | c.934C>A p.L312M | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100246545; called by muse, mutect2, varscan2
- ICAM1 | c.443T>C p.V148A | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.634); catalogued as COSV99321164; called by muse, varscan2
- IGF1R | c.761A>T p.Y254F | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV99163112; called by muse, mutect2, varscan2
- IGF2BP3 | c.913G>T p.D305Y | Missense Mutation (SNP) | VAF 18/204 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.114); catalogued as rs375047828; called by muse, mutect2
- IGSF21 | c.161T>C p.M54T | Missense Mutation (SNP) | VAF 28/156 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.12); catalogued as COSV99246260; called by muse, mutect2, varscan2
- ITIH1 | c.2591G>A p.R864Q | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT tolerated (0.62); PolyPhen benign (0.011); catalogued as rs913144777, COSV56257882; called by muse, mutect2
- ITPRIPL1 | c.1324C>A p.P442T (on ENST00000439118 / NM_001008949.3; = p.P450T on NM_178495.6) | Missense Mutation (SNP) | VAF 49/72 reads (68%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.651); catalogued as COSV100742246; called by muse, mutect2, varscan2
- JAKMIP1 | c.724G>C p.A242P | Missense Mutation (SNP) | VAF 20/286 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as COSV99290825; called by muse, mutect2
- JAKMIP3 | c.194A>T p.Q65L | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.415); catalogued as COSV100059954; called by muse, mutect2, varscan2
- JPH2 | c.413G>A p.R138H | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65906320; called by muse, mutect2, varscan2
- KANSL1 | c.3218G>A p.R1073Q (on ENST00000574590 / NM_001193465.2; = p.R1074Q on NM_015443.4) | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.71); catalogued as rs763541067, COSV52239430, COSV99290010; ClinVar: likely benign; called by muse, mutect2, varscan2
- KCNA6 | c.604G>C p.D202H | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.067); catalogued as COSV54974347, COSV99768987; called by muse, mutect2, varscan2
- KCNH1 | c.2390C>A p.P797H (on ENST00000271751 / NM_172362.3; = p.P770H on NM_002238.4) | Missense Mutation (SNP) | VAF 31/101 reads (31%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); catalogued as COSV99661555; called by muse, mutect2, varscan2
- KCNH7 | c.3053G>C p.G1018A | Missense Mutation (SNP) | VAF 122/388 reads (31%) | SIFT tolerated (0.53); PolyPhen benign (0.152); catalogued as COSV100149875; called by muse, mutect2, varscan2
- KCNJ1 | c.1060C>T p.H354Y | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.999); catalogued as COSV100131485, COSV60662819; called by muse, mutect2, varscan2
- KCNK18 | c.601C>T p.Q201* | Nonsense Mutation (SNP) | VAF 3/32 reads (9%) | catalogued as COSV100572143; called by muse, mutect2, varscan2
- KCNK2 | c.103C>A p.L35I (on ENST00000444842 / NM_001017425.3; = p.L20I on NM_014217.4) | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.844); catalogued as COSV101222340; called by muse, mutect2, varscan2
- KCNV1 | c.913G>C p.E305Q | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT tolerated (1); PolyPhen possibly damaging (0.903); catalogued as COSV99819450; called by muse, mutect2, varscan2
- KDM4D | c.421A>G p.S141G | Missense Mutation (SNP) | VAF 31/254 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.875); catalogued as COSV100624365; called by muse, mutect2, varscan2
- KDM7A | c.2284G>A p.E762K | Missense Mutation (SNP) | VAF 14/271 reads (5%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV99135157; called by muse, mutect2
- KHDRBS2 | c.134A>G p.E45G | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as COSV99837658; called by muse, mutect2, varscan2
- KHDRBS3 | c.202C>A p.P68T | Missense Mutation (SNP) | VAF 38/258 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100879021, COSV63417693; called by muse, mutect2, varscan2
- KIAA1549L | c.2257A>T p.T753S (on ENST00000321505; = p.T1050S on NM_012194.3) | Missense Mutation (SNP) | VAF 117/376 reads (31%) | SIFT tolerated (0.24); PolyPhen benign (0.006); catalogued as COSV99684471; called by muse, mutect2, varscan2
- KIAA1614 | c.2789C>A p.A930E | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs868559558, COSV62551587; called by muse, mutect2, varscan2
- KIAA1841 | c.431G>T p.G144V | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV99694232; called by muse, mutect2, varscan2
- KIF14 | c.2663T>C p.V888A | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV100951089; called by muse, mutect2, varscan2
- KIF1A | c.2153A>T p.Q718L | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV100242375; called by muse, mutect2, varscan2
- KIF20B | c.1388A>G p.Y463C | Missense Mutation (SNP) | VAF 28/128 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.81); catalogued as rs770205047, COSV99590745; called by muse, mutect2, varscan2
- KIF21B | c.4591C>A p.L1531I (on ENST00000422435 / NM_001252100.2; = p.L1518I on NM_017596.4) | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.76); catalogued as COSV100145157; called by muse, mutect2, varscan2
- KIF27 | c.564G>T p.M188I | Missense Mutation (SNP) | VAF 84/621 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.051); catalogued as COSV52829455; called by muse, mutect2, varscan2
- KMT5A | c.895C>G p.H299D | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100389621; called by muse, mutect2, varscan2
- KRT6A | c.817-1G>A p.X273_splice | Splice Site (SNP) | VAF 11/199 reads (6%) | catalogued as COSV100416979; called by muse, mutect2
- KRT75 | c.1574G>T p.S525I | Missense Mutation (SNP) | VAF 15/196 reads (8%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.987); catalogued as COSV99359655; called by muse, mutect2
- KRTAP15-1 | c.35C>A p.S12Y | Missense Mutation (SNP) | VAF 16/184 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100481664; called by muse, mutect2
- KRTAP6-2 | c.140G>T p.R47L | Missense Mutation (SNP) | VAF 18/220 reads (8%) | PolyPhen benign (0.346); catalogued as COSV100588942; called by muse, mutect2
- KRTAP9-2 | c.149C>G p.P50R | Missense Mutation (SNP) | VAF 20/158 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.401); catalogued as COSV100893252; called by muse, varscan2
- LIPI | c.1352C>A p.P451Q | Missense Mutation (SNP) | VAF 59/268 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100754023; called by muse, mutect2, varscan2
- LMBR1 | c.986G>T p.G329V | Missense Mutation (SNP) | VAF 60/174 reads (34%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); catalogued as COSV100626857; called by muse, mutect2, varscan2
- LMO7 | c.3115G>C p.D1039H (on ENST00000357063; = p.D720H on NM_005358.5) | Missense Mutation (SNP) | VAF 34/406 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100413868; called by muse, mutect2
- LRCH2 | c.2009C>A p.A670D | Missense Mutation (SNP) | VAF 24/111 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100407580; called by muse, mutect2, varscan2
- LRP12 | c.2339C>A p.S780Y | Missense Mutation (SNP) | VAF 101/615 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.641); catalogued as COSV99408376; called by muse, mutect2, varscan2
- LRP1B | c.6226G>T p.E2076* | Nonsense Mutation (SNP) | VAF 53/441 reads (12%) | catalogued as COSV101261240, COSV67197518; called by muse, mutect2, varscan2
- LRP2BP | c.178C>G p.L60V | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as rs754345592, COSV100146051; called by muse, mutect2, varscan2
- LRRC58 | c.745G>T p.V249F | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99820292; called by muse, mutect2, varscan2
- LRRC66 | c.1645A>T p.S549C | Missense Mutation (SNP) | VAF 658/863 reads (76%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.667); catalogued as COSV100603109; called by muse, mutect2, varscan2
- LRRN3 | c.947C>A p.A316D | Missense Mutation (SNP) | VAF 133/276 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV100073081, COSV100073732; called by muse, mutect2, varscan2
- LTBP1 | c.3151G>T p.G1051C (on ENST00000404816 / NM_206943.4; = p.G725C on NM_000627.4) | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99698436; called by muse, mutect2, varscan2
- LTBP3 | c.1423G>A p.E475K | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.119); catalogued as rs1199471046, COSV100100407; called by muse, mutect2, varscan2
- LYNX1-SLURP2 | c.346C>A p.P116T | Missense Mutation (SNP) | VAF 13/19 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100235831; called by muse, mutect2, varscan2
- LYPD6B | c.136A>T p.N46Y (on ENST00000409029 / NM_001317004.1; = p.N70Y on NM_177964.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 158/970 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.748); catalogued as COSV99700457; called by muse, mutect2, varscan2
- LYZL1 | c.56C>A p.S19Y | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as rs750632053, COSV100973684; called by muse, mutect2, varscan2
- MAGI1 | c.1997A>T p.Q666L | Missense Mutation (SNP) | VAF 28/131 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.596); catalogued as COSV100443161; called by muse, mutect2, varscan2
- MAGI2 | c.3337G>T p.D1113Y | Missense Mutation (SNP) | VAF 53/304 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100836646, COSV62652770; called by muse, mutect2, varscan2
- MARCHF11 | c.931C>A p.R311S | Missense Mutation (SNP) | VAF 40/139 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100198278, COSV60126013, COSV60127080; called by muse, mutect2, varscan2
- MARCHF7 | c.1682C>T p.S561L | Missense Mutation (SNP) | VAF 12/154 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99374139; called by muse, mutect2
- MARK1 | c.1249C>G p.Q417E | Missense Mutation (SNP) | VAF 24/146 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.025); catalogued as COSV100857571; called by muse, mutect2, varscan2
- MCF2 | c.290C>T p.A97V | Missense Mutation (SNP) | VAF 92/374 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.742); catalogued as COSV100645178; called by muse, mutect2, varscan2
- MDC1 | c.5224T>C p.C1742R | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.093); catalogued as COSV100903093; called by muse, mutect2, varscan2
- MED13 | c.1383G>T p.K461N | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV101181412; called by muse, mutect2, varscan2
- MED13L | c.6110A>T p.N2037I | Missense Mutation (SNP) | VAF 23/133 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV99930202; called by muse, mutect2, varscan2
- MGA | c.1051G>T p.E351* | Nonsense Mutation (SNP) | VAF 30/101 reads (30%) | catalogued as COSV54966642, COSV99581610; called by muse, mutect2, varscan2
- MID1 | c.214G>T p.G72W | Missense Mutation (SNP) | VAF 64/324 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100452217; called by muse, varscan2
- MINAR1 | c.2728C>A p.P910T | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100549284; called by muse, mutect2, varscan2
- MMP21 | c.1453T>A p.Y485N | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.549); catalogued as COSV100524032; called by muse, mutect2, varscan2
- MROH2B | c.2432G>A p.R811K | Missense Mutation (SNP) | VAF 27/108 reads (25%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.98); catalogued as COSV101270684, COSV101270931; called by muse, mutect2, varscan2
- MROH8 | c.1970G>T p.R657I | Missense Mutation (SNP) | VAF 56/457 reads (12%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.136); catalogued as COSV99457950; called by muse, mutect2, varscan2
- MRPL32 | c.244A>T p.K82* | Nonsense Mutation (SNP) | VAF 37/87 reads (43%) | catalogued as COSV99786036; called by muse, mutect2, varscan2
- MS4A6A | c.649G>T p.G217W | Missense Mutation (SNP) | VAF 256/1122 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.27); catalogued as COSV100125112; called by muse, varscan2
- MTERF3 | c.1223A>T p.Q408L | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV99749302; called by muse, mutect2
- MUC16 | c.36299A>T p.N12100I | Missense Mutation (SNP) | VAF 27/119 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.835); catalogued as rs770309663, COSV101201754; called by muse, mutect2, varscan2
- MUC16 | c.35759C>A p.T11920K | Missense Mutation (SNP) | VAF 184/442 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.943); catalogued as rs953542154, COSV101201755; called by muse, mutect2, varscan2
- MUC16 | c.31778C>A p.P10593Q | Missense Mutation (SNP) | VAF 282/677 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.976); catalogued as COSV101201757; called by muse, mutect2, varscan2
- MUC16 | c.8732G>T p.G2911V | Missense Mutation (SNP) | VAF 131/329 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.657); catalogued as COSV101201759; called by muse, mutect2, varscan2
- MUC16 | c.8731G>T p.G2911* | Nonsense Mutation (SNP) | VAF 132/329 reads (40%) | catalogued as COSV101200591, COSV101201760; called by muse, mutect2, varscan2
- MUC7 | c.143A>T p.Y48F | Missense Mutation (SNP) | VAF 95/742 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.048); catalogued as COSV100512388; called by muse, mutect2, varscan2
- MYBPC2 | c.1996G>T p.G666W | Missense Mutation (SNP) | VAF 28/134 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756397342, COSV100732028; called by muse, mutect2, varscan2
- MYH13 | c.1562C>G p.A521G | Missense Mutation (SNP) | VAF 89/278 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.374); catalogued as COSV99355494; called by muse, mutect2, varscan2
- MYH3 | c.326G>A p.R109H | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs773615398, COSV56860673; called by muse, mutect2, varscan2
- MYO18B | c.5820G>C p.K1940N | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.019); catalogued as COSV100125235; called by muse, mutect2, varscan2
- MYO3A | c.2665G>T p.V889F | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.34); PolyPhen benign (0.148); catalogued as rs1337564123, COSV99781645; called by muse, mutect2, varscan2
- MYO5A | c.3778G>T p.D1260Y | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.238); catalogued as COSV100698182; called by muse, mutect2, varscan2
- MYOCD | c.1527G>T p.E509D | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV100591445; called by muse, mutect2, varscan2
- MYOF | c.3766G>T p.G1256* | Nonsense Mutation (SNP) | VAF 20/106 reads (19%) | catalogued as COSV100826134; called by muse, mutect2, varscan2
- NAF1 | c.718-1G>C p.X240_splice | Splice Site (SNP) | VAF 14/127 reads (11%) | catalogued as COSV99919396; called by muse, mutect2, varscan2
- NAPB | c.358G>T p.A120S | Missense Mutation (SNP) | VAF 61/286 reads (21%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.919); catalogued as COSV100986015; called by muse, mutect2, varscan2
- NAV3 | c.2179G>T p.G727* | Nonsense Mutation (SNP) | VAF 120/286 reads (42%) | catalogued as COSV99894367; called by muse, mutect2, varscan2
- NAV3 | c.4366G>C p.G1456R | Missense Mutation (SNP) | VAF 41/207 reads (20%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV99895804; called by muse, mutect2, varscan2
- NAV3 | c.4367G>T p.G1456V | Missense Mutation (SNP) | VAF 41/203 reads (20%) | SIFT tolerated (0.15); PolyPhen probably damaging (1); catalogued as COSV99895808; called by muse, mutect2, varscan2
- NCF2 | c.938C>A p.P313Q | Missense Mutation (SNP) | VAF 20/154 reads (13%) | SIFT tolerated (0.43); PolyPhen benign (0.007); catalogued as COSV100838950; called by muse, mutect2, varscan2
- NDUFS1 | c.1351A>C p.I451L | Missense Mutation (SNP) | VAF 10/160 reads (6%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as COSV99261496; called by muse, mutect2
- NEFL | c.1530A>T p.E510D | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); catalogued as COSV99648194; called by muse, mutect2, varscan2
- NEGR1 | c.823A>T p.N275Y | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV100166137, COSV100166233; called by muse, mutect2, varscan2
- NEK5 | c.1075G>T p.D359Y | Missense Mutation (SNP) | VAF 31/96 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.808); catalogued as rs77133890, COSV100839167, COSV100839306; called by muse, mutect2, varscan2
- NELL1 | c.966C>A p.H322Q | Missense Mutation (SNP) | VAF 57/201 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.026); catalogued as COSV100125333; called by muse, mutect2, varscan2
- NIN | c.2024A>T p.E675V | Missense Mutation (SNP) | VAF 19/110 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as rs369112110, COSV99815321; called by muse, mutect2, varscan2
- NLGN4X | c.421G>C p.D141H | Missense Mutation (SNP) | VAF 107/613 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.066); catalogued as COSV99323987; called by muse, mutect2, varscan2
- NLRC3 | c.839T>C p.V280A | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV100073430; called by muse, mutect2, varscan2
- NPSR1 | c.662T>C p.I221T | Missense Mutation (SNP) | VAF 88/541 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV100707188; called by muse, mutect2, varscan2
- NR4A2 | c.1706G>T p.G569V | Missense Mutation (SNP) | VAF 49/80 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100277392; called by muse, mutect2, varscan2
- NR4A2 | c.1705G>T p.G569W | Missense Mutation (SNP) | VAF 47/79 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59894582; called by muse, mutect2, varscan2
- NRAP | c.4505G>A p.R1502Q (on ENST00000359988 / NM_001322945.2; = p.R1467Q on NM_006175.4) | Missense Mutation (SNP) | VAF 26/166 reads (16%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.986); catalogued as rs751856343, COSV63488845; called by muse, mutect2, varscan2
- NRXN1 | c.2323C>T p.R775C | Missense Mutation (SNP) | VAF 13/141 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs201387857, COSV100456926, COSV58479262; ClinVar: uncertain significance; called by muse, mutect2
- NRXN1 | c.1922T>A p.V641E | Missense Mutation (SNP) | VAF 106/312 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100456930; called by muse, mutect2, varscan2
- NRXN1 | c.1399G>T p.G467* | Nonsense Mutation (SNP) | VAF 219/383 reads (57%) | catalogued as COSV100456931; called by muse, mutect2, varscan2
- NRXN2 | c.972C>A p.N324K | Missense Mutation (SNP) | VAF 94/449 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99635857; called by muse, mutect2, varscan2
- NRXN3 | c.1197C>G p.N399K (on ENST00000335750 / NM_001330195.2; = p.N26K on NM_004796.6) | Missense Mutation (SNP) | VAF 48/421 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV100209243; called by muse, mutect2, varscan2
- NRXN3 | c.2440G>A p.E814K (on ENST00000335750 / NM_001330195.2; = p.E441K on NM_004796.6) | Missense Mutation (SNP) | VAF 39/133 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV59787117; called by muse, mutect2, varscan2
- NTNG1 | c.783C>A p.D261E | Missense Mutation (SNP) | VAF 45/99 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99639569; called by muse, mutect2, varscan2
- NTRK1 | c.1748G>T p.R583L | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.349); catalogued as rs762542314, COSV62324407, COSV62325705, COSV62328205; called by muse, mutect2
- NUCKS1 | c.397G>T p.D133Y | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100900808, COSV65652813; called by muse, mutect2, varscan2
- NUDT3 | c.127C>G p.P43A | Missense Mutation (SNP) | VAF 10/228 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV101657174; called by muse, mutect2
- NUP133 | c.2264C>G p.S755* | Nonsense Mutation (SNP) | VAF 31/168 reads (18%) | catalogued as COSV99773489; called by muse, mutect2, varscan2
- NUP205 | c.5224A>T p.K1742* | Nonsense Mutation (SNP) | VAF 63/243 reads (26%) | catalogued as COSV99607624; called by muse, mutect2, varscan2
- OBSL1 | c.1744G>T p.V582L | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.299); catalogued as COSV99217524; called by muse, mutect2, varscan2
- OPN5 | c.890C>A p.S297Y | Missense Mutation (SNP) | VAF 148/305 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99790050; called by muse, mutect2, varscan2
- OPRPN | c.94G>A p.G32S | Missense Mutation (SNP) | VAF 18/138 reads (13%) | SIFT tolerated, low confidence (0.47); PolyPhen possibly damaging (0.841); catalogued as rs1410722123, COSV101271100, COSV68192569; called by muse, mutect2, varscan2
- OR2A14 | c.791G>C p.R264P | Missense Mutation (SNP) | VAF 64/207 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.026); catalogued as rs1348857159, COSV101376449, COSV101376499; called by muse, mutect2, varscan2
- OR2B3 | c.764C>A p.A255D | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.745); catalogued as COSV65850848; called by muse, mutect2, varscan2
- OR4A5 | c.203A>G p.D68G | Missense Mutation (SNP) | VAF 63/244 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.452); catalogued as COSV100157311; called by muse, mutect2, varscan2
- OR4C15 | c.920G>T p.C307F (on ENST00000314644; = p.C253F on NM_001001920.2) | Missense Mutation (SNP) | VAF 225/1039 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs143375710, COSV100116111; called by muse, mutect2, varscan2
- OR4C6 | c.688G>A p.G230R | Missense Mutation (SNP) | VAF 140/607 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.946); catalogued as rs1565078863, COSV58602789; called by muse, varscan2
- OR51F1 | c.238C>A p.L80M | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.178); catalogued as COSV100598913, COSV58580296; called by muse, mutect2, varscan2
- OR52E4 | c.704G>A p.R235Q | Missense Mutation (SNP) | VAF 166/428 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.377); catalogued as rs141226100; called by muse, mutect2, varscan2
- OR52E6 | c.227C>T p.S76F | Missense Mutation (SNP) | VAF 248/701 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as rs1418790985, COSV100259560; called by muse, mutect2, varscan2
- OR52K2 | c.905G>T p.R302L | Missense Mutation (SNP) | VAF 72/735 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.187); catalogued as COSV100355856; called by muse, mutect2
- OR5AC2 | c.461G>T p.G154V | Missense Mutation (SNP) | VAF 216/543 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774695351, COSV100684498, COSV100684500; called by muse, mutect2, varscan2
- OR5D18 | c.307T>C p.F103L | Missense Mutation (SNP) | VAF 88/848 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.049); catalogued as rs766348974, COSV100450906; called by muse, mutect2, varscan2
- OR5F1 | c.127C>A p.L43I | Missense Mutation (SNP) | VAF 23/121 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs372205796, COSV53547736; called by muse, mutect2, varscan2
- OR5H15 | c.594G>T p.M198I | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.029); catalogued as COSV62947879; called by muse, mutect2, varscan2
- OR5H2 | c.608T>A p.M203K | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as COSV100788837; called by muse, mutect2, varscan2
- OR5K4 | c.645G>C p.L215F | Missense Mutation (SNP) | VAF 21/172 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.25); catalogued as COSV100721407; called by muse, mutect2, varscan2
- OR6F1 | c.710C>A p.A237D | Missense Mutation (SNP) | VAF 117/454 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57467415; called by muse, mutect2, varscan2
- OR9A2 | c.673C>T p.P225S | Missense Mutation (SNP) | VAF 73/342 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.21); catalogued as rs1409835636, COSV63306655; called by muse, mutect2, varscan2
- OR9Q2 | c.931G>T p.A311S | Missense Mutation (SNP) | VAF 39/142 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100285541, COSV61111885; called by muse, mutect2, varscan2
- OTOL1 | c.491G>T p.G164V | Missense Mutation (SNP) | VAF 23/190 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100020270, COSV60008373; called by muse, mutect2, varscan2
- OTX1 | c.56G>T p.G19V | Missense Mutation (SNP) | VAF 39/68 reads (57%) | SIFT deleterious (0.01); PolyPhen benign (0.416); catalogued as COSV56995661; called by muse, mutect2, varscan2
- OVCH1 | c.1700G>T p.S567I | Missense Mutation (SNP) | VAF 72/221 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.647); catalogued as COSV100549233; called by muse, mutect2, varscan2
- PATJ | c.2546A>T p.E849V | Missense Mutation (SNP) | VAF 25/121 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100334993; called by muse, mutect2, varscan2
- PCDH15 | c.5834A>T p.E1945V | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.601); catalogued as COSV100227837, COSV57342026; called by muse, mutect2, varscan2
- PCDH17 | c.2926C>A p.P976T | Missense Mutation (SNP) | VAF 10/109 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.724); catalogued as COSV100932055; called by muse, mutect2
- PCDH9 | c.725T>G p.V242G | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100123611; called by muse, mutect2, varscan2
- PCDHA9 | c.1951G>T p.V651L | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.914); catalogued as COSV65331603; called by muse, mutect2, varscan2
- PCDHB2 | c.1036C>A p.P346T | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.015); catalogued as COSV50564267, COSV99166694; called by muse, mutect2, varscan2
- PCDHGA2 | c.854C>A p.P285H | Missense Mutation (SNP) | VAF 45/157 reads (29%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.033); catalogued as COSV54048839, COSV99547239; called by muse, mutect2, varscan2
- PCDHGA4 | c.2408A>C p.Q803P | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV99547240; called by muse, mutect2, varscan2
- PCDHGA7 | c.2196G>T p.L732F | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.039); catalogued as COSV99547241; called by muse, mutect2, varscan2
- PCSK5 | c.4385A>T p.D1462V | Missense Mutation (SNP) | VAF 55/558 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.503); catalogued as COSV101377713; called by muse, mutect2
- PDCD10 | c.598C>G p.Q200E | Missense Mutation (SNP) | VAF 20/344 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.04); catalogued as CM143716, COSV101208510; called by muse, mutect2
- PDE11A | c.2765_2766insA p.A923Cfs*26 | Frame Shift Ins (INS) | VAF 85/157 reads (54%) | catalogued as COSV53703144; called by mutect2, varscan2*
- PDZRN3 | c.2909G>T p.G970V | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99732158; called by muse, mutect2
- PDZRN3 | c.1357G>C p.D453H | Missense Mutation (SNP) | VAF 65/134 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99732162; called by muse, mutect2, varscan2
- PDZRN4 | c.2322C>A p.S774R (on ENST00000402685 / NM_001164595.2; = p.S516R on NM_013377.4) | Missense Mutation (SNP) | VAF 28/450 reads (6%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.544); catalogued as COSV100115500; called by muse, mutect2
- PEAK1 | c.102G>T p.E34D | Missense Mutation (SNP) | VAF 59/388 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.116); catalogued as COSV100433451; called by muse, mutect2, varscan2
- PEG3 | c.1896T>A p.C632* | Nonsense Mutation (SNP) | VAF 35/108 reads (32%) | catalogued as COSV99687388, COSV99690425; called by muse, mutect2, varscan2
- PIK3R4 | c.2937G>T p.W979C | Missense Mutation (SNP) | VAF 98/258 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764488338, COSV100768600; called by muse, mutect2, varscan2
- PIK3R5 | c.35G>T p.R12L | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs779999550; called by muse, mutect2, varscan2
- PIK3R5 | c.34C>A p.R12S | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99353893; called by muse, mutect2, varscan2
- PKHD1L1 | c.3281C>G p.P1094R | Missense Mutation (SNP) | VAF 246/1130 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.048); catalogued as COSV101006852, COSV65756081; called by muse, mutect2, varscan2
- PLCH1 | c.3371C>G p.S1124* (on ENST00000340059 / NM_001130960.2; = p.S1116* on NM_014996.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 17/68 reads (25%) | catalogued as COSV100395521; called by muse, mutect2, varscan2
- PLEKHA5 | c.541A>G p.S181G | Missense Mutation (SNP) | VAF 235/561 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100164768; called by muse, mutect2, varscan2
- PLXDC2 | c.1516T>C p.S506P | Missense Mutation (SNP) | VAF 14/232 reads (6%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.996); catalogued as rs1309138543, COSV101023283; called by muse, mutect2
- PLXNA1 | c.4484G>T p.R1495L | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99304132; called by muse, mutect2, varscan2
- PLXNA4 | c.5226C>T p.C1742= | Splice Region (SNP) | VAF 98/237 reads (41%) | catalogued as rs781501987, COSV100327187, COSV58151795; called by muse, mutect2, varscan2
- PLXNA4 | c.3190C>A p.H1064N | Missense Mutation (SNP) | VAF 31/234 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100327188; called by muse, mutect2, varscan2
- PLXNA4 | c.688C>A p.P230T | Missense Mutation (SNP) | VAF 57/335 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100327191; called by muse, mutect2, varscan2
- PNPLA8 | c.1295G>T p.G432V | Missense Mutation (SNP) | VAF 37/222 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99993825; called by muse, mutect2, varscan2
- POLR3A | c.1546A>G p.K516E | Missense Mutation (SNP) | VAF 98/329 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); catalogued as COSV100965803; called by muse, mutect2, varscan2
- POLR3B | c.3111A>T p.E1037D | Missense Mutation (SNP) | VAF 108/615 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); catalogued as COSV99943869; called by muse, mutect2, varscan2
- POMK | c.30A>T p.R10S | Missense Mutation (SNP) | VAF 52/139 reads (37%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as COSV100505986; called by muse, mutect2, varscan2
- POSTN | c.1133G>T p.G378V | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV101123500, COSV101123530; called by muse, mutect2, varscan2
- POSTN | c.1132G>T p.G378* | Nonsense Mutation (SNP) | VAF 18/41 reads (44%) | catalogued as COSV101123501; called by muse, mutect2, varscan2
- PPARGC1A | c.1889G>A p.R630H | Missense Mutation (SNP) | VAF 53/473 reads (11%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as rs372413128; called by muse, mutect2, varscan2
- PPEF2 | c.918A>C p.K306N | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.984); catalogued as COSV99715010; called by muse, mutect2, varscan2
- PPP1R3A | c.1948C>A p.P650T | Missense Mutation (SNP) | VAF 171/368 reads (46%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99494341; called by muse, mutect2, varscan2
- PPP3CA | c.1441G>A p.E481K | Missense Mutation (SNP) | VAF 32/278 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100547878, COSV100548159; called by muse, mutect2, varscan2
- PRAMEF20 | c.1139C>A p.T380N | Missense Mutation (SNP) | VAF 193/474 reads (41%) | SIFT tolerated (0.3); PolyPhen benign (0.024); catalogued as rs1007127222, COSV57081511; called by muse, mutect2, varscan2
- PRB2 | c.611C>A p.P204Q | Missense Mutation (SNP) | VAF 52/1150 reads (5%) | SIFT tolerated (0.68); PolyPhen possibly damaging (0.829); catalogued as COSV66983929; called by muse, mutect2
- PRDM14 | c.841G>C p.G281R | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99400531; called by muse, mutect2, varscan2
- PRELID3B | c.257C>T p.P86L | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.679); catalogued as COSV99718219; called by muse, mutect2, varscan2
- PRKCB | c.280G>T p.A94S | Missense Mutation (SNP) | VAF 60/213 reads (28%) | SIFT tolerated (0.24); PolyPhen benign (0.011); catalogued as COSV100335420; called by muse, mutect2, varscan2
- PRKG2 | c.566A>G p.Y189C | Missense Mutation (SNP) | VAF 49/241 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.127); catalogued as rs752074471, COSV100020565; called by muse, mutect2, varscan2
- PRKX | c.239T>A p.M80K | Missense Mutation (SNP) | VAF 244/837 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV53323086, COSV99468596; called by muse, mutect2, varscan2
- PROX1 | c.1190G>T p.G397V | Missense Mutation (SNP) | VAF 13/146 reads (9%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.935); catalogued as COSV54778077; called by muse, mutect2
- PRPF40B | c.1328A>G p.N443S (on ENST00000380281; = p.N437S on NM_012272.3) | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.253); catalogued as COSV99980171; called by muse, mutect2, varscan2
- PRSS53 | c.34G>A p.A12T | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs748276565, COSV99762675; called by muse, mutect2, varscan2
- PRUNE2 | c.5716C>A p.Q1906K | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1175953536, COSV100945154; called by muse, mutect2, varscan2
- PTPRB | c.3478del p.E1160Sfs*17 | Frame Shift Del (DEL) | VAF 72/415 reads (17%) | catalogued as COSV54252129; called by mutect2, pindel, varscan2
- PTPRC | c.3826G>A p.E1276K | Missense Mutation (SNP) | VAF 75/272 reads (28%) | SIFT tolerated (0.9); PolyPhen benign (0.003); catalogued as COSV100723206; called by muse, mutect2, varscan2
- PTPRM | c.3635G>T p.R1212L | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100155194, COSV100157544; called by muse, mutect2, varscan2
- PTPRO | c.2557A>T p.R853W | Missense Mutation (SNP) | VAF 44/113 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV99841773; called by muse, mutect2, varscan2
- PTPRT | c.3161G>A p.G1054D | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV62023487; called by muse, mutect2, varscan2
- PTPRZ1 | c.1694T>A p.I565K | Missense Mutation (SNP) | VAF 20/118 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.024); catalogued as COSV101100865, COSV66438834; called by muse, mutect2, varscan2
- PTPRZ1 | c.3634C>T p.P1212S | Missense Mutation (SNP) | VAF 44/374 reads (12%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0.01); catalogued as COSV66437083; called by muse, mutect2, varscan2
- PXDNL | c.2089C>A p.P697T | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.15); catalogued as COSV99080570; called by muse, mutect2, varscan2
- RAB7A | c.302G>T p.S101I | Missense Mutation (SNP) | VAF 8/119 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.1); catalogued as COSV99414187, COSV99414336; called by muse, mutect2
- RAG1 | c.356G>T p.R119I | Missense Mutation (SNP) | VAF 67/281 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.053); catalogued as rs901852177, COSV100201173; called by muse, mutect2, varscan2
- RB1CC1 | c.1132A>T p.S378C | Missense Mutation (SNP) | VAF 119/315 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99213010; called by muse, mutect2, varscan2
- RBL2 | c.2397G>T p.L799F | Missense Mutation (SNP) | VAF 84/191 reads (44%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.521); catalogued as COSV100044069; called by muse, mutect2, varscan2
- RBM19 | c.1979G>T p.G660V | Missense Mutation (SNP) | VAF 47/159 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.105); catalogued as COSV99926845; called by muse, mutect2, varscan2
- REST | c.833G>T p.C278F | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100471352; called by muse, varscan2
- RFX3 | c.1552C>T p.Q518* | Nonsense Mutation (SNP) | VAF 101/531 reads (19%) | catalogued as COSV100175882; called by muse, mutect2, varscan2
- RIPK4 | c.1825G>T p.V609L (on ENST00000352483; = p.V561L on NM_020639.3) | Missense Mutation (SNP) | VAF 13/20 reads (65%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.783); catalogued as CM161275, COSV100205397; called by muse, mutect2, varscan2
- ROBO4 | c.2693G>T p.G898V | Missense Mutation (SNP) | VAF 30/52 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100127871; called by muse, mutect2, varscan2
- ROCK1 | c.1736A>G p.E579G | Missense Mutation (SNP) | VAF 80/856 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV101296628; called by muse, mutect2
- RPL22L1 | c.365A>T p.D122V | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.044); catalogued as COSV99860642; called by muse, mutect2
- RPL22L1 | c.274G>T p.D92Y | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99860644; called by muse, mutect2, varscan2
- RPS6KA2 | c.308G>A p.R103Q | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs749147718, COSV55826267, COSV99692157; called by muse, mutect2, varscan2
- RRAGD | c.931T>A p.Y311N | Missense Mutation (SNP) | VAF 129/270 reads (48%) | SIFT tolerated (0.13); PolyPhen benign (0.374); catalogued as COSV100784651; called by muse, mutect2, varscan2
- RRAS | c.260A>T p.Q87L | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV99882135; called by mutect2, varscan2
- RRP12 | c.3177G>T p.E1059D | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV100213505; called by muse, mutect2, varscan2
- RSRC1 | c.988G>T p.G330C | Missense Mutation (SNP) | VAF 41/191 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV99907189; called by muse, mutect2, varscan2
- RTL9 | c.2330C>T p.P777L | Missense Mutation (SNP) | VAF 27/132 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.034); catalogued as COSV101511801, COSV71826854; called by muse, mutect2, varscan2
- RUNX1T1 | c.1777C>A p.P593T (on ENST00000265814 / NM_001198628.1; = p.P566T on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as COSV99755004; called by muse, mutect2, varscan2
- RYR1 | c.5276G>T p.R1759L | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT tolerated (0.22); PolyPhen benign (0.094); catalogued as COSV100613973, COSV100617045; called by muse, mutect2, varscan2
- RYR2 | c.7234G>T p.G2412W | Missense Mutation (SNP) | VAF 105/311 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100772934, COSV63696306; called by muse, mutect2, varscan2
- RYR2 | c.10504G>A p.E3502K | Missense Mutation (SNP) | VAF 21/147 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.57); catalogued as COSV63684412; called by muse, mutect2, varscan2
- S100A7A | c.263A>G p.K88R | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as COSV100241679; called by muse, mutect2, varscan2
- SCN11A | c.4516C>G p.L1506V | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100182596; called by muse, mutect2, varscan2
- SDK2 | c.2515G>T p.E839* | Nonsense Mutation (SNP) | VAF 16/61 reads (26%) | catalogued as COSV101168661; called by muse, mutect2, varscan2
- SEC16B | c.2776G>T p.A926S | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0.011); catalogued as COSV100381421, COSV100381954; called by muse, mutect2, varscan2
- SEMA5A | c.1778C>T p.S593F | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV101228735, COSV66789964; called by muse, mutect2, varscan2
- SEMA6D | c.1057G>C p.V353L | Missense Mutation (SNP) | VAF 49/184 reads (27%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.574); catalogued as COSV100316971, COSV100317649; called by muse, mutect2, varscan2
- SERPINF1 | c.138C>G p.F46L | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT tolerated (0.55); PolyPhen benign (0.025); catalogued as COSV99628985; called by muse, varscan2
- SERPINI1 | c.986A>G p.K329R | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as COSV55515756; called by muse, varscan2
- SF1 | c.207C>A p.D69E | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.299); catalogued as COSV99918815; called by muse, mutect2, varscan2
- SHPRH | c.1772C>T p.P591L | Missense Mutation (SNP) | VAF 29/235 reads (12%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.003); catalogued as COSV99262713; called by muse, mutect2, varscan2
- SIGLEC6 | c.369G>T p.L123F | Missense Mutation (SNP) | VAF 74/197 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as COSV100585694; called by muse, mutect2, varscan2
- SKAP1 | c.55G>T p.E19* | Nonsense Mutation (SNP) | VAF 49/167 reads (29%) | catalogued as COSV100412343, COSV61153949; called by muse, mutect2, varscan2
- SLC12A1 | c.312C>A p.N104K | Missense Mutation (SNP) | VAF 24/193 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV100372589; called by muse, mutect2, varscan2
- SLC13A4 | c.625A>T p.N209Y | Missense Mutation (SNP) | VAF 33/257 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.078); catalogued as COSV100818967; called by muse, mutect2, varscan2
- SLC17A6 | c.233G>C p.G78A | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.403); catalogued as COSV99582436; called by muse, mutect2, varscan2
- SLC17A8 | c.1216G>A p.V406M | Missense Mutation (SNP) | VAF 34/447 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV100035880; called by muse, mutect2
- SLC17A8 | c.1521G>T p.Q507H | Missense Mutation (SNP) | VAF 28/152 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1323945703, COSV100035883; called by muse, mutect2, varscan2
- SLC24A2 | c.409C>A p.L137M | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99647465; called by muse, mutect2, varscan2
- SLC38A6 | c.401G>T p.G134V | Missense Mutation (SNP) | VAF 48/167 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99960108; called by muse, mutect2, varscan2
- SLC39A11 | c.247G>T p.V83F | Missense Mutation (SNP) | VAF 18/125 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.649); catalogued as COSV99724024; called by muse, mutect2, varscan2
- SLC8A1 | c.1183G>T p.E395* | Nonsense Mutation (SNP) | VAF 78/143 reads (55%) | catalogued as COSV100247466, COSV60479878; called by muse, mutect2, varscan2
- SLCO5A1 | c.2209G>C p.V737L | Missense Mutation (SNP) | VAF 49/594 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.113); catalogued as COSV99481051; called by muse, mutect2
- SLIT1 | c.2258G>T p.R753L | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as COSV56595990, COSV99822568; called by muse, mutect2, varscan2
- SLIT3 | c.4409C>G p.A1470G | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.071); catalogued as COSV100270014; called by muse, mutect2, varscan2
- SLITRK4 | c.339C>A p.H113Q | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV100567526; called by muse, mutect2, varscan2
- SMARCA2 | c.3962C>T p.T1321M | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV61810960; called by muse, mutect2
- SORCS3 | c.716C>T p.T239I | Missense Mutation (SNP) | VAF 61/414 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.613); catalogued as COSV100865664; called by muse, mutect2, varscan2
- SP4 | c.583C>G p.Q195E | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.857); catalogued as COSV99755075; called by muse, mutect2, varscan2
- SPAM1 | c.1204C>A p.P402T | Missense Mutation (SNP) | VAF 98/270 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV99773495; called by muse, mutect2, varscan2
- SPEN | c.1694C>T p.A565V | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1157570058, COSV101005626; called by muse, mutect2, varscan2
- SPEN | c.2342G>A p.R781H | Missense Mutation (SNP) | VAF 30/134 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.981); catalogued as rs778639822, COSV101005627; called by muse, mutect2, varscan2
- SPICE1 | c.1507del p.E503Kfs*17 | Frame Shift Del (DEL) | VAF 14/150 reads (9%) | catalogued as COSV55625270; called by mutect2, pindel
- SPIDR | c.1586A>G p.E529G | Missense Mutation (SNP) | VAF 58/266 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99856090; called by muse, mutect2, varscan2
- SPTA1 | c.5195A>G p.K1732R | Missense Mutation (SNP) | VAF 30/312 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as COSV100934623, COSV100935599; called by muse, mutect2
- SSBP1 | c.229G>T p.D77Y | Missense Mutation (SNP) | VAF 41/196 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99519850; called by muse, mutect2, varscan2
- ST18 | c.2782C>A p.H928N | Missense Mutation (SNP) | VAF 26/160 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.046); catalogued as COSV99391075; called by muse, mutect2, varscan2
- ST18 | c.688C>A p.L230I | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV99391076; called by muse, mutect2, varscan2
- STRC | c.5141T>C p.V1714A | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs568263767, COSV100294700; called by mutect2, varscan2
- STRN3 | c.2090T>C p.I697T (on ENST00000357479 / NM_001083893.2; = p.I613T on NM_014574.4) | Missense Mutation (SNP) | VAF 38/674 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.165); catalogued as COSV100671035; called by muse, mutect2
- STXBP4 | c.288-1G>A p.X96_splice | Splice Site (SNP) | VAF 11/49 reads (22%) | catalogued as COSV100178421; called by muse, varscan2
- STXBP4 | c.1305G>C p.E435D | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100894887, COSV64466659; called by muse, mutect2, varscan2
- SUGCT | c.135A>T p.K45N | Missense Mutation (SNP) | VAF 68/746 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.623); catalogued as COSV100004693; called by muse, mutect2
- SULT2B1 | c.697G>T p.G233C (on ENST00000201586 / NM_177973.2; = p.G218C on NM_004605.2) | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.922); catalogued as COSV99572455; called by muse, mutect2, varscan2
- SUN5 | c.486G>T p.M162I | Missense Mutation (SNP) | VAF 65/308 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV100644913, COSV62182527; called by muse, mutect2, varscan2
- SVEP1 | c.4505G>A p.C1502Y | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100239120; called by muse, mutect2, varscan2
- SYNE2 | c.4934T>C p.L1645P | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV100648512; called by muse, mutect2, varscan2
- TAB3 | c.1238G>T p.G413V | Missense Mutation (SNP) | VAF 49/160 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.899); catalogued as COSV99916845; called by muse, mutect2, varscan2
- TANC1 | c.4882G>A p.E1628K | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.129); catalogued as COSV99715245; called by muse, mutect2
- TARS1 | c.2041A>G p.K681E | Missense Mutation (SNP) | VAF 10/189 reads (5%) | SIFT tolerated (0.43); PolyPhen benign (0.049); catalogued as COSV54307803; called by muse, mutect2
- TARS3 | c.2020G>T p.G674* | Nonsense Mutation (SNP) | VAF 13/79 reads (16%) | catalogued as COSV100255053; called by muse, mutect2, varscan2
- TAS1R2 | c.689G>C p.R230P | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (0.2); PolyPhen benign (0.153); catalogued as COSV100946387; called by mutect2, varscan2
- TBX5 | c.350C>A p.A117E | Missense Mutation (SNP) | VAF 50/170 reads (29%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.947); catalogued as COSV100092194; called by muse, mutect2, varscan2
- TBXT | c.563C>A p.P188H | Missense Mutation (SNP) | VAF 70/272 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV51619396; called by muse, mutect2, varscan2
- TCF23 | c.314C>A p.A105D | Missense Mutation (SNP) | VAF 17/27 reads (63%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as COSV56078504, COSV99940419; called by muse, mutect2, varscan2
- TET1 | c.4771G>T p.G1591C | Missense Mutation (SNP) | VAF 12/133 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1424143762, COSV101018918; called by muse, mutect2
- TET1 | c.4772G>T p.G1591V | Missense Mutation (SNP) | VAF 12/120 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV101018919; called by muse, mutect2, varscan2
- TEX13A | c.1099C>G p.H367D | Missense Mutation (SNP) | VAF 59/223 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.084); catalogued as COSV100782073; called by muse, mutect2, varscan2
- TEX47 | c.736G>C p.V246L | Missense Mutation (SNP) | VAF 51/143 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.548); catalogued as COSV99787396; called by muse, mutect2, varscan2
- TG | c.6263-2A>G p.X2088_splice | Splice Site (SNP) | VAF 122/3140 reads (4%) | catalogued as COSV99603290; called by muse, mutect2
- TKTL2 | c.1781C>T p.S594L | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.022); catalogued as COSV99761749; called by muse, mutect2, varscan2
- TLR4 | c.1955A>G p.Y652C (on ENST00000355622 / NM_138554.5; = p.Y612C on NM_003266.4) | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201792813, COSV62923346; called by muse, mutect2, varscan2
- TM7SF3 | c.1064G>T p.G355V | Missense Mutation (SNP) | VAF 16/127 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100545020; called by muse, mutect2, varscan2
- TMC1 | c.1441C>A p.L481I | Missense Mutation (SNP) | VAF 97/464 reads (21%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV52772546, COSV52788600; called by muse, mutect2, varscan2
- TMC3 | c.1178G>A p.R393H | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs143697026; called by muse, mutect2
- TMEM132B | c.2510C>A p.P837H | Missense Mutation (SNP) | VAF 15/147 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.298); catalogued as COSV100170963; called by muse, mutect2, varscan2
- TMEM222 | c.404G>A p.R135H | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.14); catalogued as rs757014818, COSV65026941; called by muse, mutect2, varscan2
- TMEM74 | c.209C>A p.S70Y | Missense Mutation (SNP) | VAF 78/150 reads (52%) | SIFT tolerated (0.43); PolyPhen benign (0.006); catalogued as rs145073892, COSV99865938; called by muse, mutect2, varscan2
- TMLHE | c.12C>A p.H4Q | Missense Mutation (SNP) | VAF 52/207 reads (25%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.01); catalogued as COSV100545110; called by muse, mutect2, varscan2
- TMPRSS11F | c.638C>G p.A213G | Missense Mutation (SNP) | VAF 17/130 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.506); catalogued as rs757125206, COSV100678824; called by muse, mutect2, varscan2
- TMTC2 | c.1147C>A p.Q383K | Missense Mutation (SNP) | VAF 157/399 reads (39%) | SIFT tolerated (0.9); PolyPhen benign (0.01); catalogued as COSV100338880; called by muse, mutect2, varscan2
- TNFRSF11B | c.366G>C p.R122S | Missense Mutation (SNP) | VAF 11/171 reads (6%) | SIFT tolerated (0.7); PolyPhen benign (0.08); catalogued as COSV99816337, COSV99816980; called by muse, mutect2
- TNR | c.292C>A p.L98M | Missense Mutation (SNP) | VAF 24/112 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV54896013, COSV99691669; called by muse, mutect2, varscan2
- TNS4 | c.1207G>T p.A403S | Missense Mutation (SNP) | VAF 18/201 reads (9%) | SIFT tolerated (0.62); PolyPhen benign (0.006); catalogued as rs912729493, COSV99564167; called by muse, mutect2
- TPD52 | c.555G>A p.K185= (on ENST00000379097 / NM_001025252.3; = p.K145= on NM_005079.4 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 18/113 reads (16%) | catalogued as COSV100990900; called by muse, mutect2, varscan2
- TPP2 | c.2278C>G p.P760A | Missense Mutation (SNP) | VAF 18/218 reads (8%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV101060450; called by muse, mutect2
- TPTE2 | c.364G>A p.D122N (on ENST00000400230 / NM_199254.2; = p.D85N on NM_130785.3) | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1380842711, COSV99691018; called by mutect2, varscan2
- TRAV18 | c.102G>C p.E34D | Missense Mutation (SNP) | VAF 30/277 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.422); catalogued as rs779604623; called by muse, mutect2, varscan2
- TRIM29 | c.748C>T p.Q250* | Nonsense Mutation (SNP) | VAF 31/162 reads (19%) | catalogued as COSV100532030; called by muse, mutect2, varscan2
- TRIM42 | c.1319T>C p.V440A | Missense Mutation (SNP) | VAF 21/141 reads (15%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.967); catalogued as COSV99648850; called by muse, mutect2, varscan2
- TRIM56 | c.1949G>T p.G650V | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as COSV100047764; called by muse, mutect2, varscan2
- TRIM6 | c.181A>G p.T61A | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.083); catalogued as COSV99546854; called by muse, mutect2, varscan2
- TROAP | c.1729G>C p.V577L | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.007); catalogued as COSV57744689, COSV99227029; called by muse, varscan2
- TRRAP | c.2925G>A p.M975I | Missense Mutation (SNP) | VAF 28/501 reads (6%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV100723008; called by muse, mutect2
- TRRAP | c.2926A>T p.S976C | Missense Mutation (SNP) | VAF 30/506 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV100723009; called by muse, mutect2
- TTC17 | c.2272A>C p.N758H | Missense Mutation (SNP) | VAF 46/151 reads (30%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.768); catalogued as COSV99234474, COSV99236063; called by muse, mutect2, varscan2
- TTC27 | c.2132T>A p.I711N | Missense Mutation (SNP) | VAF 27/172 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.521); catalogued as COSV100513618; called by muse, mutect2, varscan2
- TUBA4A | c.494C>T p.S165F | Missense Mutation (SNP) | VAF 38/83 reads (46%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.912); catalogued as COSV99944994; called by muse, mutect2, varscan2
- TXNDC2 | c.177G>T p.Q59H | Missense Mutation (SNP) | VAF 97/193 reads (50%) | SIFT tolerated (0.67); PolyPhen benign (0.014); catalogued as COSV100046593; called by muse, mutect2, varscan2
- UGT2B15 | c.235A>G p.T79A | Missense Mutation (SNP) | VAF 52/224 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.02); catalogued as rs779527968, COSV100592461; called by muse, mutect2, varscan2
- UGT3A1 | c.1403C>A p.A468E | Missense Mutation (SNP) | VAF 43/135 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs141907677, COSV57095854; called by muse, mutect2, varscan2
- UNC45A | c.1654G>T p.A552S | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.991); catalogued as COSV101266053; called by mutect2, varscan2
- UNC79 | c.6904C>A p.L2302M (on ENST00000393151 / NM_001346218.2; = p.L2125M on NM_020818.5) | Missense Mutation (SNP) | VAF 26/349 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.041); catalogued as COSV99829886; called by muse, mutect2
- USH2A | c.5285C>A p.P1762H | Missense Mutation (SNP) | VAF 53/353 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.964); catalogued as COSV56439680; called by muse, mutect2, varscan2
- USH2A | c.2167G>A p.G723R | Missense Mutation (SNP) | VAF 15/143 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100230446, COSV100242898; called by muse, mutect2, varscan2
- USO1 | c.1330C>A p.L444I | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.916); catalogued as COSV99363223; called by muse, mutect2, varscan2
- USP38 | c.3043G>C p.D1015H | Missense Mutation (SNP) | VAF 75/212 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100189496; called by muse, mutect2, varscan2
- VIRMA | c.1130G>T p.G377V | Missense Mutation (SNP) | VAF 77/672 reads (11%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.999); catalogued as COSV99889505; called by muse, mutect2, varscan2
- VWA2 | c.1235G>C p.G412A | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV100073986; called by muse, mutect2, varscan2
- WASF1 | c.644A>T p.E215V | Missense Mutation (SNP) | VAF 18/275 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.189); catalogued as COSV99661516; called by muse, mutect2
- WDFY3 | c.4437G>T p.L1479F | Missense Mutation (SNP) | VAF 121/403 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99885743; called by muse, mutect2, varscan2
- WDR17 | c.556A>T p.K186* | Nonsense Mutation (SNP) | VAF 38/385 reads (10%) | catalogued as COSV99708302; called by muse, mutect2, varscan2
- WDR7 | c.613T>C p.F205L | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.031); catalogued as COSV99590480; called by muse, mutect2, varscan2
- WIPF1 | c.347A>G p.N116S | Missense Mutation (SNP) | VAF 244/445 reads (55%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as rs749246531, COSV99769487; called by muse, mutect2, varscan2
- WWP1 | c.1235C>T p.P412L | Missense Mutation (SNP) | VAF 58/424 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99617242; called by muse, mutect2
- WWP1 | c.1237A>T p.T413S | Missense Mutation (SNP) | VAF 60/420 reads (14%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.574); catalogued as COSV99617243; called by muse, mutect2
- ZAN | c.95C>A p.S32Y | Missense Mutation (SNP) | VAF 39/65 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100770375; called by muse, mutect2, varscan2
- ZBED8 | c.430G>A p.D144N | Missense Mutation (SNP) | VAF 22/191 reads (12%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.733); catalogued as COSV68824961; called by muse, mutect2, varscan2
- ZBP1 | c.1258C>T p.H420Y | Missense Mutation (SNP) | VAF 32/108 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV100473980; called by muse, varscan2
- ZBTB37 | c.497G>A p.R166Q | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (0.64); PolyPhen benign (0.034); catalogued as rs140815439; called by muse, mutect2, varscan2
- ZC3H12B | c.1886C>A p.P629H | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.121); catalogued as COSV100162059; called by muse, mutect2, varscan2
- ZC3H7A | c.1820+1G>T p.X607_splice | Splice Site (SNP) | VAF 43/102 reads (42%) | catalogued as COSV100865609; called by muse, mutect2, varscan2
- ZDHHC15 | c.283G>T p.E95* | Nonsense Mutation (SNP) | VAF 20/63 reads (32%) | catalogued as COSV100973894; called by muse, mutect2, varscan2
- ZFP42 | c.875T>A p.L292Q | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.261); catalogued as COSV100479164; called by muse, mutect2
- ZIK1 | c.733G>T p.G245W | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100277667, COSV56738657; called by muse, mutect2, varscan2
- ZKSCAN8 | c.1441C>T p.Q481* | Nonsense Mutation (SNP) | VAF 22/278 reads (8%) | catalogued as COSV100363041; called by muse, mutect2
- ZMIZ2 | c.2363C>T p.P788L | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.806); catalogued as COSV99536663, COSV99537220; called by muse, mutect2, varscan2
- ZNF106 | c.2623A>T p.S875C | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.72); catalogued as COSV99783199; called by muse, mutect2, varscan2
- ZNF112 | c.2252G>T p.C751F (on ENST00000337401 / NM_001083335.2; = p.C745F on NM_013380.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 157/407 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100496295; called by muse, mutect2, varscan2
- ZNF223 | c.754A>G p.K252E | Missense Mutation (SNP) | VAF 338/725 reads (47%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.935); catalogued as COSV101462658; called by muse, mutect2, varscan2
- ZNF257 | c.1484C>A p.A495D | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.267); catalogued as COSV101448170; called by muse, mutect2, varscan2
- ZNF354A | c.1334A>T p.K445I | Missense Mutation (SNP) | VAF 47/118 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100234653; called by muse, mutect2, varscan2
- ZNF365 | c.277A>C p.K93Q | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.238); catalogued as COSV101237998; called by muse, mutect2, varscan2
- ZNF423 | c.710G>A p.R237H (on ENST00000563137 / NM_001379286.1; = p.R229H on NM_015069.4) | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1269407799, COSV52175713, COSV52178946; called by muse, mutect2, varscan2
- ZNF429 | c.1576C>A p.Q526K | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs878915708, COSV100642052; called by muse, mutect2, varscan2
- ZNF48 | c.1588C>T p.P530S | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as COSV100198227; called by muse, mutect2, varscan2
- ZNF534 | c.327G>C p.L109F (on ENST00000332323 / NM_001143939.3; = p.L96F on NM_001143938.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.855); catalogued as COSV56514068, COSV99989793, COSV99990209; called by mutect2, varscan2
- ZNF563 | c.1129A>C p.S377R | Missense Mutation (SNP) | VAF 209/408 reads (51%) | SIFT tolerated (0.36); PolyPhen benign (0.006); catalogued as COSV99536802; called by muse, mutect2, varscan2
- ZNF597 | c.726T>A p.C242* | Nonsense Mutation (SNP) | VAF 114/184 reads (62%) | catalogued as COSV100072172; called by muse, mutect2, varscan2
- ZNF619 | c.1531G>T p.V511L | Missense Mutation (SNP) | VAF 18/133 reads (14%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV100123379; called by muse, mutect2, varscan2
- ZNF644 | c.1337G>A p.R446K | Missense Mutation (SNP) | VAF 75/229 reads (33%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.97); catalogued as COSV100494739; called by muse, mutect2, varscan2
- ZNF676 | c.1681G>A p.G561R (on ENST00000650058; = p.G529R on NM_001001411.3) | Missense Mutation (SNP) | VAF 74/198 reads (37%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.622); catalogued as rs192028972, COSV101236351; called by muse, mutect2, varscan2
- ZNF804A | c.2010T>A p.N670K | Missense Mutation (SNP) | VAF 46/270 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as COSV100170263; called by muse, mutect2, varscan2
- ZNF813 | c.788G>T p.R263I | Missense Mutation (SNP) | VAF 28/148 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as COSV101124751; called by muse, mutect2, varscan2
- ZNF823 | c.397G>A p.E133K (on ENST00000341191 / NM_001297610.2; = p.E89K on NM_017507.2) | Missense Mutation (SNP) | VAF 30/187 reads (16%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.993); catalogued as COSV100362653; called by muse, mutect2, varscan2
- ZNF98 | c.70C>G p.L24V | Missense Mutation (SNP) | VAF 148/342 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.19); catalogued as COSV100757630, COSV63339170; called by muse, mutect2, varscan2
- ZUP1 | c.1206G>T p.K402N | Missense Mutation (SNP) | VAF 81/203 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.026); catalogued as COSV100885152; called by muse, mutect2, varscan2
- ACACA | c.1799G>T p.W600L | Missense Mutation (SNP) | VAF 34/117 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANKRD44 | c.1189G>C p.E397Q | Missense Mutation (SNP) | VAF 10/206 reads (5%) | SIFT tolerated (0.15); PolyPhen benign (0.026); called by muse, mutect2
- ANXA8 | c.252G>T p.E84D | Missense Mutation (SNP) | VAF 53/333 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- ARID4A | c.3770G>T p.R1257M | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- CCDC178 | c.915dup p.E306* | Frame Shift Ins (INS) | VAF 6/23 reads (26%) | called by mutect2, pindel, varscan2
- CDH8 | c.2287G>T p.E763* | Nonsense Mutation (SNP) | VAF 8/62 reads (13%) | called by mutect2, varscan2
- CEP83 | c.403del p.R135Gfs*3 | Frame Shift Del (DEL) | VAF 58/202 reads (29%) | called by mutect2, pindel, varscan2
- CSMD2 | c.8623dup p.C2875Lfs*13 | Frame Shift Ins (INS) | VAF 6/46 reads (13%) | called by mutect2, pindel
- CYLC2 | c.489dup p.G164Rfs*2 | Frame Shift Ins (INS) | VAF 5/37 reads (14%) | called by mutect2, pindel, varscan2
- DUXA | c.557C>T p.T186I | Missense Mutation (SNP) | VAF 18/111 reads (16%) | SIFT tolerated (0.52); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- FLT4 | c.3602_3603del p.Q1201Rfs*12 | Frame Shift Del (DEL) | VAF 8/76 reads (11%) | called by mutect2, pindel, varscan2
- GABRA3 | c.1102del p.A368Lfs*13 | Frame Shift Del (DEL) | VAF 47/339 reads (14%) | called by mutect2, pindel, varscan2
- GPR39 | c.1060G>A p.V354M | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by mutect2, varscan2
- HSPA4L | c.10G>C p.V4L | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by mutect2, varscan2
- IGDCC3 | c.766G>A p.V256M | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.438); called by muse, mutect2, varscan2
- IGKV4-1 | c.58G>T p.G20W | Missense Mutation (SNP) | VAF 122/249 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, varscan2
- KARS1 | c.1574A>T p.E525V | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- KCNC1 | c.803_804del p.P268Qfs*14 | Frame Shift Del (DEL) | VAF 15/148 reads (10%) | called by mutect2, pindel, varscan2
- OR1N2 | c.644T>G p.L215R | Missense Mutation (SNP) | VAF 68/736 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.86); called by muse, mutect2
- OR2T2 | c.8T>A p.M3K | Missense Mutation (SNP) | VAF 15/142 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.441); called by mutect2, varscan2
- OR3A1 | c.483_484del p.T163Cfs*20 | Frame Shift Del (DEL) | VAF 105/515 reads (20%) | called by mutect2, pindel, varscan2
- PAQR9 | c.841T>A p.Y281N | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- PCLO | c.12571C>T p.H4191Y | Missense Mutation (SNP) | VAF 8/130 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); called by muse, mutect2
- PKD2L1 | c.650G>T p.R217L | Missense Mutation (SNP) | VAF 65/294 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.198); called by muse, mutect2, varscan2
- PTBP2 | c.1448dup p.A484Rfs*2 (on ENST00000426398 / NM_001300986.2; = p.A476Rfs*2 on NM_021190.4) | Frame Shift Ins (INS) | VAF 104/396 reads (26%) | called by pindel, varscan2
- RBFOX2 | c.979C>T p.P327S (on ENST00000438146 / NM_001349995.2; = p.P253S on NM_014309.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/163 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.84); called by muse, mutect2
- SEMG2 | c.305del p.G102Efs*24 | Frame Shift Del (DEL) | VAF 44/192 reads (23%) | called by mutect2, varscan2
- SLC13A1 | c.1412G>A p.W471* | Nonsense Mutation (SNP) | VAF 10/158 reads (6%) | called by muse, mutect2
- SLC4A10 | c.2892G>A p.M964I (on ENST00000446997 / NM_001354461.2; = p.M934I on NM_022058.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); called by muse, mutect2
- SPATA31A1 | c.3455C>A p.P1152Q | Missense Mutation (SNP) | VAF 20/501 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.64); called by muse, mutect2
- TANC2 | c.873G>C p.L291F | Missense Mutation (SNP) | VAF 16/281 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.845); called by muse, mutect2
- TBC1D8 | c.672del p.Q225Rfs*11 | Frame Shift Del (DEL) | VAF 17/40 reads (43%) | called by mutect2, pindel, varscan2
- TEX13A | c.638C>A p.P213H | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- TRAV5 | c.267G>T p.K89N | Missense Mutation (SNP) | VAF 21/224 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.049); called by muse, mutect2
- TRBV28 | c.283C>A p.L95M | Missense Mutation (SNP) | VAF 42/129 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRGV2 | c.45C>A p.A15= | Splice Region (SNP) | VAF 126/364 reads (35%) | called by muse, mutect2, varscan2
- ZNF84 | c.1307G>T p.C436F | Missense Mutation (SNP) | VAF 28/274 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZPLD1 | c.1005C>A p.S335R (on ENST00000466937 / NM_001329788.1; = p.S351R on NM_175056.2) | Missense Mutation (SNP) | VAF 18/171 reads (11%) | SIFT tolerated (0.3); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- ABCB1 | c.3246C>A p.L1082= | Silent (SNP) | VAF 45/190 reads (24%) | catalogued as COSV55957838, COSV99714465; called by muse, mutect2, varscan2
- ACSS3 | c.372T>C p.G124= | Silent (SNP) | VAF 60/267 reads (22%) | catalogued as COSV99699475; called by muse, mutect2, varscan2
- ADAMTS9 | c.2760G>T p.R920= | Silent (SNP) | VAF 43/115 reads (37%) | catalogued as COSV99900247; called by muse, mutect2, varscan2
- APOA4 | c.549C>T p.A183= | Silent (SNP) | VAF 8/105 reads (8%) | catalogued as rs1266040326, COSV100759395; called by muse, mutect2
- ARHGAP31 | c.54G>C p.A18= | Silent (SNP) | VAF 4/56 reads (7%) | catalogued as COSV99957751; called by muse, mutect2
- ARID1B | c.1842G>C p.A614= | Silent (SNP) | VAF 22/34 reads (65%) | catalogued as rs146312104, COSV51683891; called by muse, mutect2, varscan2
- ART1 | c.381G>T p.L127= | Silent (SNP) | VAF 7/16 reads (44%) | catalogued as COSV99167262; called by muse, mutect2, varscan2
- ASMT | c.411T>A p.V137= | Silent (SNP) | VAF 143/787 reads (18%) | catalogued as COSV101172545; called by muse, mutect2, varscan2
- ASTN2 | c.1953A>T p.P651= (on ENST00000313400 / NM_001365069.1; = p.P600= on NM_014010.5) | Silent (SNP) | VAF 9/64 reads (14%) | catalogued as COSV100530382; called by muse, mutect2, varscan2
- C10orf90 | c.2094G>A p.A698= | Silent (SNP) | VAF 35/127 reads (28%) | catalogued as rs933940313, COSV52951465, COSV99504432; called by muse, mutect2, varscan2
- C1orf158 | c.243C>T p.H81= | Silent (SNP) | VAF 104/1016 reads (10%) | catalogued as rs200483207, COSV55346495; called by muse, mutect2
- C9orf131 | c.2988C>A p.G996= | Silent (SNP) | VAF 36/148 reads (24%) | catalogued as COSV100398323; called by muse, varscan2
- CCP110 | c.2271C>T p.N757= | Silent (SNP) | VAF 17/160 reads (11%) | catalogued as rs375415222; called by muse, mutect2, varscan2
- CD86 | c.150G>C p.L50= (on ENST00000330540 / NM_175862.5; = p.L44= on NM_006889.4) | Silent (SNP) | VAF 78/428 reads (18%) | catalogued as COSV100054192; called by muse, mutect2, varscan2
- CDH6 | c.924A>G p.T308= | Silent (SNP) | VAF 47/287 reads (16%) | catalogued as COSV99420889; called by muse, mutect2, varscan2
- CHL1 | c.3159C>A p.G1053= (on ENST00000397491 / NM_001253387.1; = p.G1069= on NM_006614.4) | Silent (SNP) | VAF 72/193 reads (37%) | catalogued as COSV99852373; called by muse, mutect2, varscan2
- CKMT1A | c.978A>T p.A326= | Silent (SNP) | VAF 15/130 reads (12%) | catalogued as COSV100787740; called by muse, mutect2, varscan2
- CLDN8 | c.312C>T p.C104= | Silent (SNP) | VAF 82/194 reads (42%) | catalogued as COSV99730011; called by muse, mutect2, varscan2
- CLDN8 | c.165G>C p.V55= | Silent (SNP) | VAF 57/342 reads (17%) | catalogued as COSV99730013; called by muse, mutect2, varscan2
- CNGA3 | c.2082G>A p.Q694= | Silent (SNP) | VAF 32/62 reads (52%) | called by muse, mutect2, varscan2
- CNGB3 | c.630A>T p.I210= | Silent (SNP) | VAF 110/724 reads (15%) | catalogued as COSV100183093, COSV60692952; called by muse, mutect2, varscan2
- CNNM3 | c.1932G>A p.L644= | Silent (SNP) | VAF 24/55 reads (44%) | catalogued as COSV100562796; called by muse, mutect2, varscan2
- CNTN6 | c.2136A>C p.G712= | Silent (SNP) | VAF 64/162 reads (40%) | catalogued as rs1229103195, COSV100611865; called by muse, mutect2, varscan2
- COL4A5 | c.4515G>T p.T1505= | Silent (SNP) | VAF 31/130 reads (24%) | catalogued as rs370327284, COSV100089613, COSV60360182; called by muse, mutect2, varscan2
- CTNNA2 | c.1185C>A p.T395= | Silent (SNP) | VAF 106/230 reads (46%) | catalogued as COSV100562065; called by muse, mutect2, varscan2
- DNAH11 | c.1701T>A p.A567= | Silent (SNP) | VAF 53/223 reads (24%) | catalogued as COSV100180950; called by muse, mutect2, varscan2
- DRD5 | c.1062C>T p.L354= | Silent (SNP) | VAF 19/63 reads (30%) | catalogued as COSV100432041; called by muse, mutect2, varscan2
- DST | c.15099A>C p.T5033= (on ENST00000361203 / NM_001374722.1; = p.T2621= on NM_015548.5) | Silent (SNP) | VAF 29/218 reads (13%) | catalogued as COSV99760122; called by muse, mutect2, varscan2
- EDEM1 | c.1404A>T p.R468= | Silent (SNP) | VAF 20/294 reads (7%) | catalogued as COSV99849411; called by muse, mutect2
- EPB41L3 | c.2046G>C p.P682= | Silent (SNP) | VAF 17/131 reads (13%) | catalogued as rs549355143, COSV100550302, COSV59460167; called by muse, mutect2, varscan2
- ESX1 | c.1170C>T p.H390= | Silent (SNP) | VAF 12/60 reads (20%) | catalogued as COSV101006508; called by muse, varscan2
- EZH2 | c.2052T>A p.I684= (on ENST00000460911 / NM_001203247.2; = p.I689= on NM_004456.5) | Silent (SNP) | VAF 116/786 reads (15%) | catalogued as COSV100236880; called by muse, mutect2, varscan2
- FBXL4 | c.1194G>A p.E398= | Silent (SNP) | VAF 86/166 reads (52%) | catalogued as rs762144154, COSV100014376; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FCRL4 | c.1296C>A p.G432= | Silent (SNP) | VAF 8/56 reads (14%) | called by muse, mutect2, varscan2
- FLG | c.12057G>A p.A4019= | Silent (SNP) | VAF 41/168 reads (24%) | catalogued as rs370295034; called by muse, mutect2, varscan2
- FLG | c.10113C>A p.S3371= | Silent (SNP) | VAF 203/578 reads (35%) | catalogued as COSV100912231; called by muse, mutect2, varscan2
- GDAP1 | c.753C>T p.L251= | Silent (SNP) | VAF 11/103 reads (11%) | catalogued as rs1285748573, COSV99619885; called by muse, mutect2, varscan2
- GINM1 | c.162G>T p.G54= | Silent (SNP) | VAF 29/73 reads (40%) | catalogued as rs773278724, COSV100805374; called by muse, mutect2, varscan2
- GPAM | c.1941A>T p.V647= | Silent (SNP) | VAF 80/340 reads (24%) | catalogued as COSV100788437; called by muse, mutect2, varscan2
- GRIK2 | c.2100C>G p.S700= | Silent (SNP) | VAF 64/134 reads (48%) | catalogued as COSV100029472; called by muse, mutect2, varscan2
- GRIP1 | c.453G>T p.V151= | Silent (SNP) | VAF 75/656 reads (11%) | catalogued as COSV99671065; called by muse, mutect2, varscan2
- GRM3 | c.2427G>T p.L809= | Silent (SNP) | VAF 20/216 reads (9%) | catalogued as COSV100862564, COSV100862913; called by muse, mutect2
- GSX1 | c.564G>A p.E188= | Silent (SNP) | VAF 10/27 reads (37%) | catalogued as rs1213445066, COSV100262634; called by muse, mutect2, varscan2
- GTF2IRD2 | c.2439C>T p.S813= | Silent (SNP) | VAF 24/157 reads (15%) | catalogued as COSV100736470; called by muse, mutect2, varscan2
- HDAC9 | c.2406C>A p.A802= | Silent (SNP) | VAF 58/306 reads (19%) | catalogued as COSV101287600; called by muse, mutect2, varscan2
- HSD17B10 | c.255G>T p.V85= | Silent (SNP) | VAF 29/129 reads (22%) | catalogued as COSV99395017; called by muse, mutect2, varscan2
- HTR7 | c.267G>T p.T89= | Silent (SNP) | VAF 7/66 reads (11%) | catalogued as COSV53287357, COSV99520282; called by muse, mutect2, varscan2
- INPPL1 | c.2706C>T p.A902= | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as COSV99996659; called by muse, mutect2, varscan2
- KCNB2 | c.1191G>T p.V397= | Silent (SNP) | VAF 84/227 reads (37%) | catalogued as COSV101579017; called by muse, mutect2, varscan2
- KIF15 | c.4047G>A p.L1349= | Silent (SNP) | VAF 7/47 reads (15%) | catalogued as COSV100393267; called by muse, mutect2, varscan2
- KIT | c.2865G>T p.V955= | Silent (SNP) | VAF 32/148 reads (22%) | catalogued as COSV99855368; called by muse, mutect2, varscan2
- KRT79 | c.357C>T p.V119= | Silent (SNP) | VAF 30/98 reads (31%) | catalogued as COSV100398562; called by muse, mutect2, varscan2
- LCE1C | c.192T>G p.S64= | Silent (SNP) | VAF 30/74 reads (41%) | catalogued as COSV100908487; called by muse, mutect2, varscan2
- LGALS9B | c.705G>A p.G235= (on ENST00000423676 / NM_001367292.1; = p.G234= on NM_001042685.2) | Silent (SNP) | VAF 5/13 reads (38%) | catalogued as COSV100163047; called by mutect2, varscan2
- LIM2 | c.132G>T p.R44= | Silent (SNP) | VAF 22/57 reads (39%) | catalogued as COSV99702489; called by muse, varscan2
- LRRC30 | c.603C>T p.I201= | Silent (SNP) | VAF 15/119 reads (13%) | catalogued as rs202241153, COSV67301591; called by muse, mutect2, varscan2
- LRRC32 | c.1539C>T p.F513= | Silent (SNP) | VAF 7/70 reads (10%) | catalogued as COSV99477366; called by muse, mutect2, varscan2
- LRRTM3 | c.387C>T p.F129= | Silent (SNP) | VAF 40/360 reads (11%) | catalogued as COSV100791923; called by muse, mutect2, varscan2
- MACC1 | c.798G>A p.S266= | Silent (SNP) | VAF 18/222 reads (8%) | catalogued as rs371205090; called by muse, mutect2
- MAGEB18 | c.852C>A p.V284= | Silent (SNP) | VAF 28/119 reads (24%) | called by muse, mutect2, varscan2
- MFSD1 | c.606G>A p.L202= | Silent (SNP) | VAF 46/174 reads (26%) | catalogued as COSV99964089; called by muse, mutect2, varscan2
- MKS1 | c.1188G>A p.V396= | Silent (SNP) | VAF 8/29 reads (28%) | catalogued as rs1460798211, COSV99836777; called by muse, mutect2
- MPDZ | c.4095T>A p.A1365= | Silent (SNP) | VAF 75/178 reads (42%) | catalogued as COSV100057635; called by muse, mutect2, varscan2
- MROH2B | c.2433G>A p.R811= | Silent (SNP) | VAF 27/104 reads (26%) | catalogued as rs1039311137, COSV101270930; called by muse, mutect2, varscan2
- MUC16 | c.8247T>C p.S2749= | Silent (SNP) | VAF 71/459 reads (15%) | catalogued as COSV101201761; called by muse, mutect2, varscan2
- MYH4 | c.2760G>A p.E920= | Silent (SNP) | VAF 162/382 reads (42%) | catalogued as rs1013328773, COSV99702271; called by muse, mutect2, varscan2
- MYO18B | c.7572C>T p.I2524= | Silent (SNP) | VAF 5/95 reads (5%) | catalogued as COSV59131832; called by muse, mutect2
- MYO3A | c.1203T>A p.T401= | Silent (SNP) | VAF 18/290 reads (6%) | catalogued as COSV99781642; called by muse, mutect2
- NALCN | c.3579C>A p.R1193= | Silent (SNP) | VAF 26/112 reads (23%) | catalogued as COSV99217820; called by muse, mutect2, varscan2
- NEO1 | c.2949C>G p.A983= | Silent (SNP) | VAF 14/49 reads (29%) | catalogued as COSV56076908, COSV99982814; called by muse, mutect2, varscan2
- NIT2 | c.285C>T p.N95= | Silent (SNP) | VAF 6/56 reads (11%) | catalogued as rs1279376134, COSV101237137; called by mutect2, varscan2
- NPFFR2 | c.1413C>T p.S471= | Silent (SNP) | VAF 16/156 reads (10%) | catalogued as COSV100441300; called by muse, mutect2
- NPY5R | c.310C>T p.L104= | Silent (SNP) | VAF 38/396 reads (10%) | catalogued as COSV100642946; called by muse, mutect2
- NRROS | c.1707G>T p.S569= | Silent (SNP) | VAF 10/23 reads (43%) | catalogued as COSV100145634; called by muse, mutect2, varscan2
- NRXN3 | c.1035C>G p.V345= | Silent (SNP) | VAF 29/121 reads (24%) | catalogued as COSV100209242; called by muse, mutect2, varscan2
- NTM | c.195G>T p.R65= | Silent (SNP) | VAF 47/192 reads (24%) | catalogued as COSV100869561; called by muse, mutect2, varscan2
- OBSCN | c.3787T>C p.L1263= | Silent (SNP) | VAF 19/119 reads (16%) | catalogued as rs758898223, COSV99484445; called by muse, mutect2, varscan2
- OR10G4 | c.543G>T p.P181= | Silent (SNP) | VAF 218/669 reads (33%) | catalogued as COSV100304998, COSV57976449; called by muse, mutect2, varscan2
- OR10G7 | c.543G>T p.P181= | Silent (SNP) | VAF 144/1074 reads (13%) | catalogued as COSV57867848; called by muse, mutect2, varscan2
- OR13C5 | c.30G>T p.V10= | Silent (SNP) | VAF 48/259 reads (19%) | catalogued as COSV101053182, COSV66165424; called by muse, mutect2, varscan2
- OR14C36 | c.84C>A p.S28= | Silent (SNP) | VAF 150/438 reads (34%) | catalogued as COSV100507661, COSV58601882; called by muse, mutect2, varscan2
- OR4C16 | c.21G>C p.V7= | Silent (SNP) | VAF 78/271 reads (29%) | catalogued as COSV100114258; called by muse, mutect2, varscan2
- OR52I2 | c.873G>T p.A291= | Silent (SNP) | VAF 86/275 reads (31%) | catalogued as COSV100443021; called by muse, mutect2, varscan2
- OR5C1 | c.306C>T p.A102= | Silent (SNP) | VAF 47/277 reads (17%) | catalogued as COSV101030609; called by muse, mutect2, varscan2
- PAPPA2 | c.4608G>A p.L1536= | Silent (SNP) | VAF 53/248 reads (21%) | catalogued as COSV100868669; called by muse, mutect2, varscan2
- PCDHB14 | c.1536C>T p.H512= | Silent (SNP) | VAF 12/38 reads (32%) | catalogued as rs1332522933, COSV53389929, COSV99506297; called by muse, mutect2, varscan2
- PCLO | c.11535C>T p.T3845= | Silent (SNP) | VAF 253/895 reads (28%) | catalogued as rs755981458, COSV61661560; called by muse, mutect2, varscan2
- PCLO | c.6729A>C p.I2243= | Silent (SNP) | VAF 42/192 reads (22%) | catalogued as COSV100437944; called by muse, mutect2, varscan2
- PCYT1B | c.1008C>A p.P336= | Silent (SNP) | VAF 13/29 reads (45%) | catalogued as COSV100770868; called by muse, mutect2, varscan2
- PES1 | c.108G>T p.R36= | Silent (SNP) | VAF 8/79 reads (10%) | catalogued as COSV100073349; called by muse, mutect2
- PLXNA1 | c.4485G>T p.R1495= | Silent (SNP) | VAF 5/27 reads (19%) | catalogued as COSV99304135; called by muse, mutect2, varscan2
- PLXNA4 | c.2608C>A p.R870= | Silent (SNP) | VAF 20/65 reads (31%) | catalogued as COSV58113989; called by muse, mutect2, varscan2
- POTED | c.291G>A p.K97= | Silent (SNP) | VAF 49/102 reads (48%) | catalogued as COSV100202960, COSV100203242; called by muse, mutect2, varscan2
- POTEF | c.2761C>T p.L921= | Silent (SNP) | VAF 61/134 reads (46%) | catalogued as rs759576363, COSV100665358, COSV100665429; called by muse, mutect2, varscan2
- PPP6R2 | c.957G>T p.L319= | Silent (SNP) | VAF 10/39 reads (26%) | catalogued as COSV99324821; called by muse, mutect2, varscan2
- PROX1 | c.1191G>T p.G397= | Silent (SNP) | VAF 14/150 reads (9%) | catalogued as COSV99800232; called by muse, mutect2
- PTCHD3 | c.954G>T p.R318= | Silent (SNP) | VAF 12/56 reads (21%) | catalogued as COSV101438971; called by mutect2, varscan2
- PTGS1 | c.945G>A p.L315= | Silent (SNP) | VAF 10/76 reads (13%) | catalogued as COSV99793553; called by muse, mutect2, varscan2
- PTPRZ1 | c.2253G>A p.P751= | Silent (SNP) | VAF 34/562 reads (6%) | catalogued as rs201224372, COSV101100866; called by muse, mutect2
- PTPRZ1 | c.3633C>A p.T1211= | Silent (SNP) | VAF 45/376 reads (12%) | catalogued as rs764061939, COSV101100868; called by muse, mutect2, varscan2
- PXDNL | c.2088C>A p.S696= | Silent (SNP) | VAF 9/24 reads (38%) | catalogued as COSV100686464, COSV62498358; called by muse, mutect2, varscan2
- RELN | c.5013C>A p.G1671= | Silent (SNP) | VAF 18/81 reads (22%) | catalogued as rs758902738, COSV100632873; called by muse, mutect2, varscan2
- RFX4 | c.1008G>T p.V336= (on ENST00000392842 / NM_213594.3; = p.V242= on NM_032491.6) | Silent (SNP) | VAF 38/187 reads (20%) | catalogued as COSV99986371; called by muse, mutect2, varscan2
- RNASE2 | c.378G>A p.A126= | Silent (SNP) | VAF 41/465 reads (9%) | catalogued as rs147476821; called by muse, mutect2
- RNF26 | c.1134G>A p.K378= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as COSV100264944; called by muse, mutect2
- RORA | c.1275A>G p.A425= (on ENST00000335670 / NM_134261.3; = p.A450= on NM_002943.3) | Silent (SNP) | VAF 13/87 reads (15%) | catalogued as rs780518456, COSV99833093; called by muse, mutect2, varscan2
- RP1 | c.1695T>G p.G565= | Silent (SNP) | VAF 17/138 reads (12%) | catalogued as COSV55118441; called by muse, mutect2, varscan2
- RYR1 | c.1164G>T p.S388= | Silent (SNP) | VAF 22/126 reads (17%) | catalogued as COSV100617043; called by muse, mutect2, varscan2
- SCN3B | c.399C>A p.P133= | Silent (SNP) | VAF 27/102 reads (26%) | catalogued as COSV100173875; called by muse, mutect2, varscan2
- SEC16A | c.5118C>T p.A1706= | Silent (SNP) | VAF 4/13 reads (31%) | catalogued as COSV99260237; called by muse, mutect2, varscan2
- SEC31B | c.2244C>T p.A748= | Silent (SNP) | VAF 60/163 reads (37%) | catalogued as COSV100947477; called by muse, mutect2, varscan2
- SETD7 | c.303T>C p.D101= | Silent (SNP) | VAF 21/142 reads (15%) | catalogued as COSV99918710; called by muse, mutect2, varscan2
- SGPP1 | c.1050A>G p.L350= | Silent (SNP) | VAF 12/95 reads (13%) | catalogued as COSV99906019; called by muse, mutect2, varscan2
- SI | c.3489T>C p.H1163= | Silent (SNP) | VAF 80/325 reads (25%) | catalogued as COSV100017221; called by muse, mutect2, varscan2
- SIGLEC9 | c.285G>T p.G95= | Silent (SNP) | VAF 18/87 reads (21%) | catalogued as COSV99143382; called by muse, mutect2, varscan2
- SKIL | c.1275C>G p.L425= | Silent (SNP) | VAF 24/310 reads (8%) | catalogued as COSV99378555; called by muse, mutect2
- SLA | c.720C>A p.T240= (on ENST00000338087 / NM_001045556.3; = p.T280= on NM_006748.4) | Silent (SNP) | VAF 212/361 reads (59%) | catalogued as COSV99603292; called by muse, mutect2, varscan2
- SLC11A1 | c.390T>A p.P130= | Silent (SNP) | VAF 15/133 reads (11%) | catalogued as COSV99262489; called by muse, mutect2, varscan2
- SLC14A2 | c.2211A>T p.S737= | Silent (SNP) | VAF 33/265 reads (12%) | catalogued as COSV99676199; called by muse, mutect2, varscan2
- SLC18A3 | c.336G>T p.R112= | Silent (SNP) | VAF 4/31 reads (13%) | catalogued as rs368610030; called by mutect2, varscan2
- SLC1A3 | c.1024C>A p.R342= | Silent (SNP) | VAF 26/152 reads (17%) | catalogued as COSV54314880, COSV99468288; called by muse, mutect2, varscan2
- SLC2A14 | c.711C>A p.L237= | Silent (SNP) | VAF 55/164 reads (34%) | catalogued as COSV100534047; called by muse, mutect2, varscan2
- SLC39A12 | c.138G>T p.L46= | Silent (SNP) | VAF 27/154 reads (18%) | catalogued as COSV101070181; called by muse, mutect2, varscan2
- SLC9C1 | c.102G>A p.R34= | Silent (SNP) | VAF 17/51 reads (33%) | catalogued as COSV99998846; called by muse, mutect2, varscan2
- SLFN5 | c.915G>A p.V305= | Silent (SNP) | VAF 47/190 reads (25%) | catalogued as rs374598061; called by muse, mutect2, varscan2
- SLIT3 | c.3474C>A p.I1158= | Silent (SNP) | VAF 9/24 reads (38%) | catalogued as COSV100270017; called by muse, mutect2, varscan2
- SLITRK2 | c.564C>T p.L188= | Silent (SNP) | VAF 9/53 reads (17%) | catalogued as COSV100158225; called by muse, mutect2, varscan2
- SORCS3 | c.2658G>C p.A886= | Silent (SNP) | VAF 54/291 reads (19%) | catalogued as COSV100863832, COSV63793931, COSV63794340; called by muse, mutect2, varscan2
- SORL1 | c.2973G>T p.G991= | Silent (SNP) | VAF 56/204 reads (27%) | catalogued as COSV99495528; called by muse, mutect2, varscan2
- SPATA31A1 | c.3456A>T p.P1152= | Silent (SNP) | VAF 20/498 reads (4%) | catalogued as COSV100885076; called by muse, mutect2
- SPATA31D1 | c.1392G>A p.L464= | Silent (SNP) | VAF 16/206 reads (8%) | catalogued as rs760958685, COSV100783059; called by muse, mutect2
- SRGAP3 | c.165G>T p.R55= | Silent (SNP) | VAF 31/66 reads (47%) | catalogued as COSV100841453; called by muse, mutect2, varscan2
42 further variants in this file (0 protein-altering or splice-affecting, 26 silent, 16 other) are not listed here.
